Somatic mutation profile of tumor specimen C3N-01533-03 (aliquot CPT0096450006) from CPTAC case C3N-01533, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 73.3 years (26,761 days).
Specimen C3N-01533-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72e21b5f-108c-45b4-b37d-ef047e87d697.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01533-71 (Blood Derived Normal), aliquot CPT0096470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64f75a53-7d7e-43b2-88d2-7df81165eb6e

The open-access MAF lists 1,256 somatic variants for this specimen: 806 protein-altering or splice-affecting, 408 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 737, Silent 408, Nonsense Mutation 47, Intron 22, Splice Region 11, Splice Site 7, RNA 6, 5'Flank 5, 3'UTR 4, 3'Flank 3, 5'UTR 2, Frame Shift Ins 2.

Variants (750 of 1,256; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CP | c.2253G>A p.W751* | Nonsense Mutation (SNP) | VAF 46/268 reads (17%) | catalogued as rs1559940237; ClinVar: pathogenic; called by muse, varscan2
- DICER1 | c.5428G>A p.D1810N | Missense Mutation (SNP) | VAF 149/329 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775912475, COSV58615443, COSV58615662, COSV58615890; called by muse, mutect2, varscan2
- DNAH5 | c.10615C>T p.R3539C | Missense Mutation (SNP) | VAF 114/297 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1304504006, CM091938, COSV54205813; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- EGFR | c.2257C>T p.P753S | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); catalogued as rs121913231, COSV51778029; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs193922185, CM118485, COSV100353754; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- HBD | chr11:5232765 C>T | 3'Flank (SNP) | VAF 46/195 reads (24%) | catalogued as rs35324967, CR920792; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NRAS | c.181C>A p.Q61K | Missense Mutation (SNP) | VAF 238/441 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.709); catalogued as rs121913254, COSV54736310, COSV54743343, COSV54752117; ClinVar: not provided / uncertain significance / likely pathogenic / pathogenic / drug response; called by muse, mutect2, varscan2
- ABCA13 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 47/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs546968040; called by muse, mutect2, varscan2
- ABCB1 | c.944G>A p.W315* | Nonsense Mutation (SNP) | VAF 74/465 reads (16%) | catalogued as rs1189919755; called by muse, mutect2, varscan2
- ABI3BP | c.1378C>T p.P460S | Missense Mutation (SNP) | VAF 41/237 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.738); catalogued as COSV52528689; called by muse, mutect2, varscan2
- AC008676.3 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 245/377 reads (65%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as rs912062768, COSV56636749; called by muse, mutect2, varscan2
- ACO1 | c.664G>T p.G222C | Missense Mutation (SNP) | VAF 147/225 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745839445; called by muse, mutect2, varscan2
- ACOX2 | c.1588G>A p.E530K | Missense Mutation (SNP) | VAF 60/287 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.509); catalogued as rs772660285, COSV57148096; called by muse, mutect2, varscan2
- ADAM7 | c.1957G>A p.E653K | Missense Mutation (SNP) | VAF 73/411 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.411); catalogued as COSV51546060; called by muse, mutect2, varscan2
- ADGRB3 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 60/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1363049892, COSV65419101; called by muse, mutect2, varscan2
- ADGRD2 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 77/335 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.037); catalogued as rs953434144; called by muse, mutect2, varscan2
- AK7 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 89/227 reads (39%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV50869762; called by muse, mutect2, varscan2
- AKR1B15 | c.136C>T p.R46C | Missense Mutation (SNP) | VAF 90/297 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs757106375, COSV71151096; called by muse, mutect2, varscan2
- ALDOB | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100878868; called by muse, mutect2, varscan2
- ALPG | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 105/430 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0.003); catalogued as rs770596019; called by muse, mutect2, varscan2
- ALPP | c.1351G>A p.E451K | Missense Mutation (SNP) | VAF 75/439 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as COSV67396264; called by muse, mutect2, varscan2
- AMER1 | c.2476C>T p.P826S | Missense Mutation (SNP) | VAF 108/296 reads (36%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.922); catalogued as COSV57655826; called by muse, mutect2, varscan2
- ANK3 | c.11068G>A p.G3690R | Missense Mutation (SNP) | VAF 97/277 reads (35%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs1252227510; called by muse, mutect2, varscan2
- ANK3 | c.868C>T p.R290* | Nonsense Mutation (SNP) | VAF 55/197 reads (28%) | catalogued as COSV55079698; called by muse, mutect2, varscan2
- ANKRD18B | c.2766G>A p.T922= | Splice Region (SNP) | VAF 72/104 reads (69%) | catalogued as rs757047319, COSV52094247; called by muse, mutect2, varscan2
- ANKRD35 | c.2506G>A p.E836K | Missense Mutation (SNP) | VAF 308/764 reads (40%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.974); catalogued as rs1309545536; called by muse, mutect2
- APOB | c.9851C>T p.S3284F | Missense Mutation (SNP) | VAF 70/371 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV51951697; called by muse, mutect2, varscan2
- ARGFX | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 67/313 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV57681637; called by muse, mutect2, varscan2
- ARHGAP22 | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 71/197 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs374843400, COSV50932392; called by muse, mutect2, varscan2
- ARID3A | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 129/265 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.562); catalogued as rs537786817; called by muse, mutect2, varscan2
- ARPP21 | c.830G>A p.R277Q | Missense Mutation (SNP) | VAF 44/250 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs535388566, COSV51802472; called by muse, mutect2, varscan2
- ASB15 | c.313G>A p.E105K | Missense Mutation (SNP) | VAF 168/371 reads (45%) | SIFT deleterious (0.04); PolyPhen benign (0.21); catalogued as COSV51923900; called by muse, mutect2, varscan2
- ATG16L1 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 115/281 reads (41%) | SIFT tolerated (0.34); PolyPhen benign (0.161); catalogued as rs779324767, COSV61464744; called by muse, mutect2, varscan2
- B3GAT1 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 136/463 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs575105698; called by muse, mutect2, varscan2
- BICD2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 97/324 reads (30%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.466); catalogued as rs765057014; called by muse, mutect2, varscan2
- BICDL2 | c.755G>A p.S252N | Missense Mutation (SNP) | VAF 68/265 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.12); catalogued as rs1199689554; called by muse, mutect2, varscan2
- C11orf16 | c.*25A>G | Splice Region (SNP) | VAF 75/151 reads (50%) | catalogued as rs1246334764; called by muse, mutect2, varscan2
- C8B | c.1742C>T p.S581L | Missense Mutation (SNP) | VAF 73/429 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as COSV64777271; called by muse, mutect2, varscan2
- CA10 | c.256C>T p.R86C | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as rs767808441, COSV53350762; called by muse, mutect2, varscan2
- CACNA1E | c.3148G>A p.E1050K | Missense Mutation (SNP) | VAF 97/551 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.041); catalogued as rs1428423503, COSV62397535; called by muse, mutect2, varscan2
- CACNA1E | c.5074G>A p.E1692K | Missense Mutation (SNP) | VAF 231/450 reads (51%) | SIFT tolerated (0.12); PolyPhen benign (0.094); catalogued as rs770455581, COSV62437732; called by muse, varscan2
- CACNA1E | c.6709G>A p.E2237K (on ENST00000367573 / NM_001205293.3; = p.E2194K on NM_000721.4) | Missense Mutation (SNP) | VAF 90/556 reads (16%) | SIFT tolerated (0.46); PolyPhen benign (0.165); catalogued as rs375491167; called by muse, mutect2, varscan2
- CADM2 | c.718G>A p.E240K (on ENST00000407528 / NM_001167674.2; = p.E242K on NM_153184.4) | Missense Mutation (SNP) | VAF 98/294 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67358651; called by muse, mutect2, varscan2
- CAPN9 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 201/292 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55231800, COSV55240471; called by muse, mutect2, varscan2
- CCDC141 | c.3206G>A p.R1069K | Missense Mutation (SNP) | VAF 66/287 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.101); catalogued as COSV55371681; called by muse, mutect2, varscan2
- CCDC144A | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1301024320; called by muse, mutect2
- CCDC158 | c.2042G>A p.R681K | Missense Mutation (SNP) | VAF 118/175 reads (67%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.647); catalogued as rs949347806; called by muse, mutect2, varscan2
- CCDC33 | c.829G>A p.G277R | Missense Mutation (SNP) | VAF 63/265 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs199609536; called by muse, mutect2, varscan2
- CCDC92 | c.898C>T p.P300S | Missense Mutation (SNP) | VAF 118/487 reads (24%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.007); catalogued as rs1348825981; called by muse, mutect2, varscan2
- CD84 | c.388C>T p.R130C | Missense Mutation (SNP) | VAF 87/341 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.96); catalogued as rs766261094, COSV60870815; called by muse, mutect2, varscan2
- CDH2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 76/292 reads (26%) | SIFT tolerated (0.6); PolyPhen probably damaging (0.973); catalogued as rs1274623800; called by muse, mutect2, varscan2
- CDH4 | c.1552G>A p.E518K | Missense Mutation (SNP) | VAF 577/902 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.795); catalogued as COSV64654911; called by muse, mutect2, varscan2
- CDH6 | c.1286G>A p.R429K | Missense Mutation (SNP) | VAF 37/193 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as COSV99418001; called by muse, mutect2, varscan2
- CEACAM18 | c.406G>A p.G136R | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.44); PolyPhen benign (0.036); catalogued as rs1354684507; called by muse, mutect2, varscan2
- CECR2 | c.781C>T p.R261C (on ENST00000342247 / NM_001290047.2; = p.R98C on NM_001290046.1) | Missense Mutation (SNP) | VAF 67/349 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs923281762, COSV52835225; called by muse, mutect2, varscan2
- CEP70 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 51/257 reads (20%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs1411716390; called by muse, mutect2, varscan2
- CERS4 | c.668C>T p.S223F | Missense Mutation (SNP) | VAF 126/305 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52166092; called by muse, mutect2, varscan2
- CETN1 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 49/294 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as rs768969475, COSV59121657; called by muse, mutect2, varscan2
- CFAP61 | c.953G>A p.G318E | Missense Mutation (SNP) | VAF 33/104 reads (32%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV55632545; called by muse, mutect2, varscan2
- CFAP69 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 15/357 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as rs1378719540, COSV60185437; called by muse, mutect2
- CFTR | c.1466C>T p.S489L | Missense Mutation (SNP) | VAF 74/489 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397508211, CM970276, COSV50041123; called by muse, mutect2, varscan2
- CFTR | c.4129G>A p.D1377N | Missense Mutation (SNP) | VAF 77/303 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs150683293, CM950257; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CHRDL1 | c.721C>T p.Q241* (on ENST00000372045; = p.Q247* on NM_145234.4) | Nonsense Mutation (SNP) | VAF 88/138 reads (64%) | catalogued as COSV54326021; called by muse, mutect2, varscan2
- CILP2 | c.692G>A p.R231Q | Missense Mutation (SNP) | VAF 222/465 reads (48%) | SIFT tolerated (0.76); PolyPhen benign (0.01); catalogued as rs778001472, COSV52273736; called by muse, varscan2
- CLEC4D | c.30G>A p.L10= | Splice Region (SNP) | VAF 41/155 reads (26%) | catalogued as COSV55231234; called by muse, mutect2, varscan2
- CLEC5A | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 53/318 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.006); catalogued as rs1197523757, COSV69397002; called by muse, mutect2, varscan2
- CLU | c.701C>T p.P234L | Missense Mutation (SNP) | VAF 158/466 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs771318822, COSV57066327; called by muse, mutect2, varscan2
- CLUH | c.2266C>T p.P756S (on ENST00000435359; = p.P795S on NM_015229.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 97/208 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV70929231; called by muse, mutect2, varscan2
- CNBD1 | c.1234C>T p.P412S | Missense Mutation (SNP) | VAF 55/345 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775205356, COSV101582292; called by muse, mutect2, varscan2
- CNTNAP2 | c.2527G>A p.E843K | Missense Mutation (SNP) | VAF 46/326 reads (14%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as rs1295258604, COSV62241726; called by muse, mutect2, varscan2
- CNTNAP4 | c.3094C>T p.H1032Y | Missense Mutation (SNP) | VAF 93/183 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.012); catalogued as COSV56663738, COSV56690517; called by muse, mutect2, varscan2
- COBL | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 69/498 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs779477077; called by muse, mutect2, varscan2
- COL10A1 | c.275G>A p.G92E | Missense Mutation (SNP) | VAF 100/290 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs761767424; called by muse, mutect2, varscan2
- COL11A1 | c.4403G>A p.G1468E | Missense Mutation (SNP) | VAF 62/381 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867331843, COSV62172298, COSV62172442; called by muse, mutect2, varscan2
- COL11A1 | c.4303G>A p.G1435R | Missense Mutation (SNP) | VAF 47/297 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267597897; called by muse, mutect2, varscan2
- COL22A1 | c.3647G>A p.G1216E | Missense Mutation (SNP) | VAF 121/404 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323811; called by muse, mutect2, varscan2
- COL4A2 | c.4033G>A p.E1345K | Missense Mutation (SNP) | VAF 43/278 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.374); catalogued as rs1407965001, COSV100847369, COSV64625464, COSV64628369; called by muse, mutect2, varscan2
- COL4A3 | c.2863G>A p.G955R | Missense Mutation (SNP) | VAF 122/273 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs771818723; called by muse, mutect2, varscan2
- COL4A4 | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 45/257 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61637273; called by muse, mutect2, varscan2
- COL4A5 | c.1672G>A p.G558S | Missense Mutation (SNP) | VAF 87/172 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM010193; called by muse, mutect2, varscan2
- COL6A5 | c.6796G>A p.E2266K (on ENST00000312481; = p.E2262K on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/172 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.073); catalogued as rs1242504947, COSV55208131; called by muse, mutect2, varscan2
- COL7A1 | c.5602G>A p.E1868K | Missense Mutation (SNP) | VAF 71/376 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as COSV60393784; called by muse, mutect2, varscan2
- COLQ | c.616C>T p.P206S | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV67524181; called by muse, mutect2, varscan2
- CPNE9 | c.514C>T p.L172F | Missense Mutation (SNP) | VAF 52/248 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99808187; called by muse, mutect2, varscan2
- CPXM2 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 48/261 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV53870226; called by muse, mutect2, varscan2
- CRYBG2 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 64/388 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766680992; called by muse, mutect2, varscan2
- CSH2 | c.86C>A p.T29N | Missense Mutation (SNP) | VAF 117/1109 reads (11%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.543); catalogued as COSV61080566; called by muse, mutect2, varscan2
- CSMD1 | c.7835G>A p.G2612E (on ENST00000520002; = p.G2611E on NM_033225.6) | Missense Mutation (SNP) | VAF 63/302 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs376096771, COSV59397124; called by muse, mutect2, varscan2
- CSMD1 | c.5429G>A p.R1810Q (on ENST00000520002; = p.R1809Q on NM_033225.6) | Missense Mutation (SNP) | VAF 118/226 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs770980133, COSV59315770; called by muse, mutect2, varscan2
- CSMD2 | c.9682G>A p.E3228K | Missense Mutation (SNP) | VAF 337/591 reads (57%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.999); catalogued as rs891390487, COSV53954045; called by muse, mutect2, varscan2
- CSMD2 | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 82/473 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.602); catalogued as COSV53903509; called by muse, mutect2, varscan2
- CSMD3 | c.1933G>A p.E645K (on ENST00000297405 / NM_001363185.1; = p.E541K on NM_052900.3) | Missense Mutation (SNP) | VAF 61/349 reads (17%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.998); catalogued as rs780733307, COSV52256469, COSV99852540; called by muse, mutect2, varscan2
- CTAGE1 | c.1411C>T p.P471S | Missense Mutation (SNP) | VAF 39/144 reads (27%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.705); catalogued as rs267605127, COSV66942971; called by muse, mutect2, varscan2
- CUX2 | c.3929A>G p.E1310G | Missense Mutation (SNP) | VAF 28/452 reads (6%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs555556704; called by muse, mutect2
- CXCR2 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 59/363 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1298311873, COSV59279763; called by muse, mutect2, varscan2
- CYP2C8 | c.350G>A p.G117E | Missense Mutation (SNP) | VAF 41/213 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV104428885, COSV64876343; called by muse, mutect2, varscan2
- CYP2C9 | c.380C>T p.S127F | Missense Mutation (SNP) | VAF 87/285 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs530507053, COSV99582951; called by muse, mutect2, varscan2
- CYP3A7 | c.91G>A p.G31R | Missense Mutation (SNP) | VAF 48/341 reads (14%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.849); catalogued as rs1344365349; called by muse, mutect2, varscan2
- CYP8B1 | c.881C>G p.A294G | Missense Mutation (SNP) | VAF 173/436 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.371); catalogued as COSV60226064; called by muse, mutect2, varscan2
- DAB1 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 96/187 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs758139028; called by muse, mutect2, varscan2
- DBX1 | c.935C>T p.S312L | Missense Mutation (SNP) | VAF 68/288 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.9); catalogued as rs763778118, COSV57054453; called by muse, mutect2, varscan2
- DCAF8L1 | c.1696G>A p.D566N | Missense Mutation (SNP) | VAF 87/249 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.046); catalogued as rs1277200484, COSV71595218; called by muse, mutect2, varscan2
- DCC | c.2842C>T p.P948S | Missense Mutation (SNP) | VAF 98/292 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59095533; called by muse, mutect2, varscan2
- DCC | c.2954C>T p.T985I | Missense Mutation (SNP) | VAF 36/185 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59129228; called by muse, mutect2, varscan2
- DCDC1 | c.4976A>G p.N1659S (on ENST00000597505 / NM_001367979.1; = p.N766S on NM_020869.3) | Missense Mutation (SNP) | VAF 190/322 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1429594095; called by muse, mutect2, varscan2
- DDC | c.670G>A p.E224K | Missense Mutation (SNP) | VAF 58/412 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.02); catalogued as rs1279635735; called by muse, mutect2, varscan2
- DEDD2 | c.837C>G p.F279L | Missense Mutation (SNP) | VAF 215/579 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.258); catalogued as COSV60141152; called by muse, mutect2, varscan2
- DGKA | c.1342G>A p.A448T | Missense Mutation (SNP) | VAF 118/194 reads (61%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.643); catalogued as rs1383471112; called by muse, mutect2, varscan2
- DLG1 | c.2011C>T p.P671S | Missense Mutation (SNP) | VAF 56/255 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100015531; called by muse, mutect2, varscan2
- DLGAP2 | c.1016C>T p.S339F | Missense Mutation (SNP) | VAF 107/667 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1014805098; called by muse, mutect2, varscan2
- DNAH11 | c.1408C>T p.R470C | Missense Mutation (SNP) | VAF 56/325 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs374144841, COSV60959431, COSV60970653; called by muse, mutect2, varscan2
- DNAH14 | c.10417G>A p.G3473S (on ENST00000445597; = p.G4481S on NM_001367479.1) | Missense Mutation (SNP) | VAF 116/488 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as rs1382717879; called by muse, mutect2, varscan2
- DNAH3 | c.9346G>A p.E3116K | Missense Mutation (SNP) | VAF 92/699 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54550653; called by muse, mutect2, varscan2
- DNAH5 | c.2065C>T p.H689Y | Missense Mutation (SNP) | VAF 71/175 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.426); catalogued as COSV54229374; called by muse, mutect2, varscan2
- DNAJC5B | c.362C>T p.T121M | Missense Mutation (SNP) | VAF 75/410 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); catalogued as rs200440195, COSV52536291; called by muse, mutect2, varscan2
- DPP10 | c.2233G>A p.A745T | Missense Mutation (SNP) | VAF 123/274 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.439); catalogued as COSV59733683; called by muse, mutect2, varscan2
- DRD5 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 233/359 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100431675; called by muse, mutect2, varscan2
- DRICH1 | c.223C>T p.R75C | Missense Mutation (SNP) | VAF 69/304 reads (23%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs371978440; called by muse, mutect2, varscan2
- DSCAML1 | c.3325G>A p.E1109K (on ENST00000321322; = p.E1049K on NM_020693.4) | Missense Mutation (SNP) | VAF 74/287 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201776853, COSV58385125; called by muse, mutect2, varscan2
- DSP | c.7585G>A p.D2529N | Missense Mutation (SNP) | VAF 141/387 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV101131890; called by muse, mutect2, varscan2
- EFCAB12 | c.265G>A p.V89I | Missense Mutation (SNP) | VAF 93/422 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as rs753416184; called by muse, mutect2, varscan2
- EFEMP1 | c.1421G>A p.G474E | Missense Mutation (SNP) | VAF 76/366 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.497); catalogued as COSV62615429; called by muse, mutect2, varscan2
- EFNA5 | c.479C>T p.P160L | Missense Mutation (SNP) | VAF 54/247 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs369853743; called by muse, mutect2, varscan2
- ELOVL4 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 143/333 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs532735834, COSV63953631; called by muse, mutect2, varscan2
- ENPP3 | c.2614G>A p.E872K | Missense Mutation (SNP) | VAF 87/136 reads (64%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as COSV62955173; called by muse, mutect2, varscan2
- EPB41L4A | c.1633G>A p.D545N | Missense Mutation (SNP) | VAF 67/252 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.669); catalogued as rs772727938; called by muse, mutect2, varscan2
- EPB41L4B | c.1442C>T p.S481L | Missense Mutation (SNP) | VAF 72/283 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.01); catalogued as rs768403763, COSV65801850; called by muse, mutect2, varscan2
- EPHA10 | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 214/426 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598587, COSV60404142; called by muse, mutect2, varscan2
- ERBB4 | c.1781C>T p.P594L | Missense Mutation (SNP) | VAF 168/402 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53518029, COSV53544235; called by muse, mutect2, varscan2
- ERICH3 | c.1387A>G p.T463A | Missense Mutation (SNP) | VAF 212/419 reads (51%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs750159594; called by muse, mutect2, varscan2
- ERICH3 | c.775C>T p.R259C | Missense Mutation (SNP) | VAF 56/359 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs769315284, COSV58600498; called by muse, mutect2, varscan2
- F13A1 | c.2077G>A p.E693K | Missense Mutation (SNP) | VAF 66/386 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.103); catalogued as COSV53564402; called by muse, varscan2
- FAM170A | c.236G>A p.S79N | Missense Mutation (SNP) | VAF 145/226 reads (64%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.603); catalogued as rs768638581, COSV58926232; called by muse, mutect2, varscan2
- FAM3D | c.445G>A p.D149N | Missense Mutation (SNP) | VAF 59/260 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs761002325, COSV62559043; called by muse, mutect2, varscan2
- FAM47C | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 188/281 reads (67%) | SIFT tolerated (0.54); PolyPhen benign (0.208); catalogued as COSV63723912; called by muse, mutect2, varscan2
- FAM71E2 | c.1546C>T p.P516S | Missense Mutation (SNP) | VAF 61/304 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.078); catalogued as rs532156001; called by muse, mutect2, varscan2
- FAM9C | c.484G>A p.G162R | Missense Mutation (SNP) | VAF 136/206 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as COSV61775817; called by muse, mutect2, varscan2
- FAT4 | c.8351C>T p.P2784L | Missense Mutation (SNP) | VAF 61/312 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV58705986; called by muse, mutect2, varscan2
- FBP1 | c.359C>T p.P120L | Missense Mutation (SNP) | VAF 68/259 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM164864; called by muse, mutect2, varscan2
- FCGR2A | c.146G>A p.W49* (on ENST00000271450 / NM_001136219.3; = p.W48* on NM_021642.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 212/431 reads (49%) | catalogued as rs370320754; called by muse, mutect2, varscan2
- FCRL6 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 69/316 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.098); catalogued as rs868843314; called by muse, mutect2, varscan2
- FGF12 | c.328C>T p.P110S (on ENST00000454309 / NM_021032.5; = p.P48S on NM_004113.6) | Missense Mutation (SNP) | VAF 54/298 reads (18%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.986); catalogued as COSV53186124; called by muse, mutect2, varscan2
- FHAD1 | c.1796C>T p.S599L | Missense Mutation (SNP) | VAF 64/362 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs771774392; called by muse, mutect2, varscan2
- FLG | c.5477G>A p.G1826E | Missense Mutation (SNP) | VAF 236/626 reads (38%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.996); catalogued as rs768149687; called by muse, mutect2, varscan2
- FLRT2 | c.1843G>A p.D615N | Missense Mutation (SNP) | VAF 250/365 reads (68%) | SIFT tolerated (0.3); PolyPhen benign (0.238); catalogued as rs866102871, COSV58150691; called by muse, mutect2, varscan2
- FLT1 | c.2008C>T p.H670Y | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as COSV56735152; called by muse, mutect2, varscan2
- FLT3 | c.1159C>T p.R387* | Nonsense Mutation (SNP) | VAF 128/279 reads (46%) | catalogued as COSV54044057, COSV54071888; called by muse, mutect2, varscan2
- FRAS1 | c.4021C>T p.P1341S | Missense Mutation (SNP) | VAF 65/347 reads (19%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV53635555; called by muse, mutect2, varscan2
- FREM2 | c.5293C>T p.R1765C | Missense Mutation (SNP) | VAF 46/276 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as rs770772406, COSV54826790; called by muse, mutect2, varscan2
- FRY | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 141/290 reads (49%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs771312453, COSV66568488, COSV66570042; called by muse, mutect2, varscan2
- FYB1 | c.1978C>T p.P660S (on ENST00000351578 / NM_199335.5; = p.P706S on NM_001465.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/261 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.941); catalogued as COSV60958199; called by muse, mutect2
- FYB1 | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 153/350 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV60941035; called by muse, mutect2, varscan2
- G6PC | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs779548820, COSV53831761; called by muse, mutect2, varscan2
- GALNT17 | c.365C>T p.S122L | Missense Mutation (SNP) | VAF 76/565 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as rs750663732, COSV100355269, COSV61167202; called by muse, mutect2, varscan2
- GAS2 | c.317C>T p.S106F | Missense Mutation (SNP) | VAF 141/262 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53408326; called by muse, mutect2, varscan2
- GATA5 | c.192G>A p.W64* | Nonsense Mutation (SNP) | VAF 548/848 reads (65%) | catalogued as rs1211587640, COSV53347480; called by muse, varscan2
- GC | c.1183G>A p.E395K | Missense Mutation (SNP) | VAF 37/191 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.062); catalogued as COSV56738391; called by muse, mutect2, varscan2
- GHR | c.876-1G>A p.X292_splice | Splice Site (SNP) | VAF 66/174 reads (38%) | catalogued as CS971753, COSV50107294; called by muse, mutect2, varscan2
- GIPC1 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 202/483 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1179101468; called by muse, mutect2, varscan2
- GKAP1 | c.110G>A p.R37Q | Missense Mutation (SNP) | VAF 77/259 reads (30%) | SIFT tolerated (0.32); PolyPhen benign (0.059); catalogued as rs761607485; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1826G>A p.G609E | Missense Mutation (SNP) | VAF 125/713 reads (18%) | SIFT deleterious, low confidence (0); catalogued as rs753834422; called by muse, mutect2, varscan2
- GON4L | c.2242C>T p.Q748* | Nonsense Mutation (SNP) | VAF 124/486 reads (26%) | catalogued as COSV55190249; called by muse, mutect2, varscan2
- GPC3 | c.1535G>A p.G512E | Missense Mutation (SNP) | VAF 99/162 reads (61%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs1162314906; called by muse, mutect2, varscan2
- GPR83 | c.1025C>A p.P342H | Missense Mutation (SNP) | VAF 99/326 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1160257723; called by muse, varscan2
- GRM7 | c.1275G>A p.M425I | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); catalogued as COSV63143356; called by muse, mutect2, varscan2
- GSDMD | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 120/613 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.242); catalogued as rs763781279, COSV99369433; called by muse, mutect2, varscan2
- GTF3C1 | c.2150C>T p.S717L | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62244340; called by muse, mutect2, varscan2
- HDAC9 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 104/273 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as rs1042313151, COSV101286773; called by muse, mutect2, varscan2
- HLA-DQA1 | c.612G>A p.W204* | Nonsense Mutation (SNP) | VAF 170/481 reads (35%) | catalogued as rs756288178; called by muse, mutect2, varscan2
- HNF4A | c.1273G>A p.G425R | Missense Mutation (SNP) | VAF 156/405 reads (39%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.069); catalogued as COSV57389401; called by muse, varscan2
- HSPA6 | c.1777G>A p.E593K | Missense Mutation (SNP) | VAF 158/415 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.902); catalogued as rs1204675341; called by muse, mutect2, varscan2
- IFIT1B | c.461G>A p.G154E | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.862); catalogued as COSV65663758; called by muse, mutect2
- IFNA1 | c.383G>A p.R128K | Missense Mutation (SNP) | VAF 55/163 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs781606132; called by muse, mutect2, varscan2
- IFRD1 | c.1297C>T p.R433* | Nonsense Mutation (SNP) | VAF 54/433 reads (12%) | catalogued as rs781354249, COSV50045191; called by muse, mutect2, varscan2
- IGSF10 | c.272A>G p.N91S | Missense Mutation (SNP) | VAF 67/358 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766366919; called by muse, mutect2, varscan2
- IL37 | c.492G>A p.W164* | Nonsense Mutation (SNP) | VAF 82/362 reads (23%) | catalogued as COSV99635966; called by muse, mutect2, varscan2
- IL3RA | c.709C>T p.R237C | Missense Mutation (SNP) | VAF 115/334 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.301); catalogued as rs753510585, COSV58430644; called by muse, mutect2, varscan2
- IQUB | c.206C>T p.S69L | Missense Mutation (SNP) | VAF 64/489 reads (13%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.001); catalogued as COSV61237172; called by muse, mutect2, varscan2
- ITPRID1 | c.759G>A p.M253I | Missense Mutation (SNP) | VAF 84/475 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.018); catalogued as rs1416281664; called by muse, mutect2, varscan2
- JMY | c.1092G>A p.M364I | Missense Mutation (SNP) | VAF 64/327 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.083); catalogued as COSV68662040; called by muse, mutect2, varscan2
- KAZN | c.1681C>T p.R561* | Nonsense Mutation (SNP) | VAF 89/442 reads (20%) | catalogued as rs1457454827; called by muse, mutect2, varscan2
- KCNF1 | c.211G>A p.D71N | Missense Mutation (SNP) | VAF 93/391 reads (24%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.999); catalogued as rs1185412337, COSV54463557; called by muse, mutect2, varscan2
- KCNH1 | c.1835G>A p.G612E (on ENST00000271751 / NM_172362.3; = p.G585E on NM_002238.4) | Missense Mutation (SNP) | VAF 98/524 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55073402; called by muse, mutect2, varscan2
- KCNK10 | c.1125G>A p.M375I | Missense Mutation (SNP) | VAF 293/450 reads (65%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.593); catalogued as COSV56640333; called by muse, varscan2
- KCNMA1 | c.3755C>T p.P1252L | Missense Mutation (SNP) | VAF 52/204 reads (25%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.995); catalogued as rs201074275; called by muse, mutect2, varscan2
- KCTD16 | c.736C>T p.H246Y | Missense Mutation (SNP) | VAF 188/307 reads (61%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as COSV72578696; called by muse, mutect2, varscan2
- KIF16B | c.1784G>A p.G595E | Missense Mutation (SNP) | VAF 82/198 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1256755681, COSV61706463; called by muse, mutect2, varscan2
- KLHDC9 | c.26G>A p.R9Q | Missense Mutation (SNP) | VAF 159/536 reads (30%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0); catalogued as COSV63509688; called by muse, mutect2, varscan2
- KLHL1 | c.317G>A p.G106E | Missense Mutation (SNP) | VAF 94/440 reads (21%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.015); catalogued as COSV100916933; called by muse, mutect2, varscan2
- KLHL31 | c.1030G>A p.G344R | Missense Mutation (SNP) | VAF 77/461 reads (17%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.483); catalogued as rs757869286, COSV63881855; called by muse, mutect2, varscan2
- KMT2B | c.6767C>T p.P2256L | Missense Mutation (SNP) | VAF 123/327 reads (38%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs767078867; called by muse, mutect2, varscan2
- KRBOX1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 59/335 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs766716237, COSV101070299, COSV67466798; called by muse, mutect2, varscan2
- KRT8 | c.26C>T p.S9F | Missense Mutation (SNP) | VAF 172/335 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV53177366; called by muse, mutect2, varscan2
- KRT84 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 77/150 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs747574789; called by muse, mutect2, varscan2
- L3MBTL4 | c.1258C>T p.R420C | Missense Mutation (SNP) | VAF 72/277 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.341); catalogued as rs749722357, COSV53114604; called by muse, mutect2, varscan2
- LIPA | c.229+1G>A p.X77_splice | Splice Site (SNP) | VAF 39/133 reads (29%) | catalogued as rs201104126, CS122002, COSV51079675; called by muse, mutect2, varscan2
- LMO4 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 57/380 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.06); catalogued as rs532279574, COSV65170501; called by muse, mutect2, varscan2
- LONRF2 | c.2137C>T p.Q713* | Nonsense Mutation (SNP) | VAF 219/506 reads (43%) | catalogued as COSV101111026; called by muse, mutect2, varscan2
- LOXHD1 | c.941C>T p.S314F | Missense Mutation (SNP) | VAF 97/220 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59668563; called by muse, mutect2, varscan2
- LOXHD1 | c.788G>A p.R263K | Missense Mutation (SNP) | VAF 50/231 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV100190404, COSV59665172; called by muse, mutect2, varscan2
- LRFN2 | c.1404G>A p.M468I | Missense Mutation (SNP) | VAF 75/192 reads (39%) | SIFT tolerated (0.27); PolyPhen benign (0.401); catalogued as rs1413582796, COSV57826925; called by muse, mutect2, varscan2
- LRP1B | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 51/209 reads (24%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs145092192, COSV67197624, COSV67249343; called by muse, mutect2, varscan2
- LRRK1 | c.3905C>T p.S1302F | Missense Mutation (SNP) | VAF 96/317 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.897); catalogued as COSV52623413; called by muse, mutect2, varscan2
- MAGEB6 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 44/108 reads (41%) | SIFT tolerated (0.2); PolyPhen benign (0.177); catalogued as COSV66872786; called by muse, varscan2
- MAP3K21 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 279/379 reads (74%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs753079246, COSV64045846; called by muse, mutect2, varscan2
- MAPT | c.1889C>T p.S630F (on ENST00000262410 / NM_001377265.1; = p.S238F on NM_005910.5) | Missense Mutation (SNP) | VAF 234/539 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52249335; called by muse, mutect2, varscan2
- MARCHF10 | c.523C>T p.P175S | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.115); catalogued as COSV60890605; called by muse, mutect2, varscan2
- MCM4 | c.1183C>T p.R395* | Nonsense Mutation (SNP) | VAF 43/275 reads (16%) | catalogued as rs1470097733, COSV50621053; called by muse, mutect2, varscan2
- MCMDC2 | c.1244C>T p.S415L | Missense Mutation (SNP) | VAF 62/358 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV58040844; called by muse, mutect2, varscan2
- MCTP1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 125/184 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV100387827, COSV56514376, COSV56536253; called by muse, mutect2, varscan2
- MDN1 | c.4955C>T p.S1652F | Missense Mutation (SNP) | VAF 102/247 reads (41%) | SIFT tolerated (0.14); PolyPhen benign (0.009); catalogued as rs779551988, COSV101020734; called by muse, mutect2, varscan2
- MFSD2A | c.1073C>T p.P358L (on ENST00000372809 / NM_001136493.3; = p.P345L on NM_032793.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 136/410 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1368639501; called by muse, mutect2, varscan2
- MOCS1 | c.1272G>C p.W424C | Missense Mutation (SNP) | VAF 62/291 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as COSV99225689; called by muse, mutect2, varscan2
- MORC1 | c.1225G>A p.E409K | Missense Mutation (SNP) | VAF 107/286 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); catalogued as COSV51721449; called by muse, mutect2, varscan2
- MSR1 | c.1175G>A p.G392E | Missense Mutation (SNP) | VAF 146/412 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50530256; called by muse, mutect2, varscan2
- MTUS1 | c.3212C>T p.S1071L (on ENST00000262102 / NM_001363061.1; = p.S237L on NM_020749.4) | Missense Mutation (SNP) | VAF 52/328 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs370634502; called by muse, mutect2, varscan2
- MUC16 | c.24803C>T p.S8268F | Missense Mutation (SNP) | VAF 78/399 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.943); catalogued as rs1330676451, COSV67461695; called by muse, mutect2, varscan2
- MUC16 | c.23086G>A p.V7696M | Missense Mutation (SNP) | VAF 81/352 reads (23%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.001); catalogued as rs770085186, COSV101198328, COSV67474468; called by muse, mutect2, varscan2
- MUC16 | c.20751G>A p.M6917I | Missense Mutation (SNP) | VAF 151/343 reads (44%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.009); catalogued as rs756802696, COSV67453508; called by muse, mutect2, varscan2
- MUC17 | c.7015C>T p.P2339S | Missense Mutation (SNP) | VAF 101/512 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV60309036; called by muse, mutect2, varscan2
- MUC17 | c.11021C>T p.S3674L | Missense Mutation (SNP) | VAF 282/655 reads (43%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.979); catalogued as COSV60300453; called by muse, mutect2, varscan2
- MUC17 | c.11534C>T p.P3845L | Missense Mutation (SNP) | VAF 136/439 reads (31%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as COSV60303921; called by muse, mutect2, varscan2
- MUC2 | c.2203G>A p.G735R | Missense Mutation (SNP) | VAF 164/275 reads (60%) | SIFT tolerated (0.45); catalogued as rs781080417; called by muse, mutect2, varscan2
- MUC3A | c.770C>T p.S257F | Missense Mutation (SNP) | VAF 88/535 reads (16%) | SIFT deleterious, low confidence (0.03); catalogued as rs773629742; called by muse, mutect2, varscan2
- MUC4 | c.11236C>T p.P3746S | Missense Mutation (SNP) | VAF 85/592 reads (14%) | SIFT tolerated, low confidence (0.69); PolyPhen possibly damaging (0.65); catalogued as rs1192833264; called by muse, mutect2, varscan2
- MYH2 | c.3800C>T p.S1267L | Missense Mutation (SNP) | VAF 130/211 reads (62%) | SIFT deleterious (0.05); PolyPhen benign (0.026); catalogued as COSV99820220; called by muse, mutect2, varscan2
- MYH4 | c.5326G>A p.E1776K | Missense Mutation (SNP) | VAF 66/293 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV55121340; called by muse, mutect2, varscan2
- MYH6 | c.1548G>A p.M516I | Missense Mutation (SNP) | VAF 119/279 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.214); catalogued as COSV62455068; called by muse, mutect2, varscan2
- MYH8 | c.3255G>A p.K1085= | Splice Region (SNP) | VAF 20/109 reads (18%) | catalogued as COSV67959126; called by muse, mutect2, varscan2
- MYH8 | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 46/179 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); catalogued as COSV67960793; called by muse, mutect2, varscan2
- MYH8 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 121/211 reads (57%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV67970345; called by muse, mutect2, varscan2
- MYO18B | c.5401C>T p.R1801W | Missense Mutation (SNP) | VAF 58/275 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs980051048, COSV59138727; called by muse, mutect2, varscan2
- MYO5B | c.2365G>A p.G789R | Missense Mutation (SNP) | VAF 60/272 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs371467730; called by muse, mutect2, varscan2
- MYOF | c.5566C>T p.P1856S | Missense Mutation (SNP) | VAF 61/248 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.794); catalogued as rs1307949683, COSV100825293, COSV63712513; called by muse, mutect2, varscan2
- NAV2 | c.1676C>T p.S559F (on ENST00000396087 / NM_001244963.2; = p.S536F on NM_145117.5) | Missense Mutation (SNP) | VAF 164/333 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as COSV62316341; called by muse, mutect2, varscan2
- NBEA | c.8506C>T p.H2836Y | Missense Mutation (SNP) | VAF 63/384 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.046); catalogued as COSV59765154; called by muse, mutect2, varscan2
- NCAN | c.1852C>T p.P618S | Missense Mutation (SNP) | VAF 109/497 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs746874998, COSV99387858; called by muse, mutect2, varscan2
- NCAPH | c.1733T>C p.L578S | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.74); PolyPhen benign (0.334); catalogued as rs1413577472; called by muse, mutect2
- NDNF | c.1030G>A p.E344K | Missense Mutation (SNP) | VAF 70/381 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.298); catalogued as rs182647465; called by muse, mutect2, varscan2
- NEUROD1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 62/315 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54551146; called by muse, mutect2, varscan2
- NFATC1 | c.412G>A p.D138N | Missense Mutation (SNP) | VAF 103/239 reads (43%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); catalogued as rs775904780; called by muse, mutect2, varscan2
- NID2 | c.986C>T p.P329L | Missense Mutation (SNP) | VAF 89/311 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.191); catalogued as rs771135026; called by muse, mutect2, varscan2
- NLRP10 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 193/325 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100149937; called by muse, mutect2, varscan2
- NLRP4 | c.1327G>A p.E443K | Missense Mutation (SNP) | VAF 119/420 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.122); catalogued as COSV56711854, COSV56721724; called by muse, mutect2, varscan2
- NLRP9 | c.2258C>T p.P753L | Missense Mutation (SNP) | VAF 135/371 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.13); catalogued as rs866694886; called by muse, mutect2, varscan2
- NLRP9 | c.653C>T p.S218F | Missense Mutation (SNP) | VAF 58/392 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV60460431; called by muse, mutect2, varscan2
- NNT | c.1076C>T p.P359L | Missense Mutation (SNP) | VAF 105/281 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); catalogued as COSV52924098; called by muse, mutect2, varscan2
- NPTX2 | c.1006G>A p.E336K | Missense Mutation (SNP) | VAF 100/668 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.67); catalogued as rs141241960, COSV55716182; called by muse, mutect2, varscan2
- NREP | c.53G>A p.R18Q | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1192701096, COSV67401246; called by muse, mutect2, varscan2
- NRG2 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 92/246 reads (37%) | SIFT tolerated (0.14); PolyPhen benign (0.358); catalogued as rs1450359745; called by muse, mutect2, varscan2
- NT5E | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 119/366 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57627951; called by muse, mutect2, varscan2
- NUP62 | c.937C>T p.P313S | Missense Mutation (SNP) | VAF 71/417 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs756113021; called by muse, mutect2, varscan2
- NWD1 | c.3061G>A p.D1021N | Missense Mutation (SNP) | VAF 108/414 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as COSV60352393; called by muse, mutect2, varscan2
- NXN | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 77/264 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1334684450, COSV61093802; called by muse, mutect2, varscan2
- NXPH1 | c.190C>T p.R64C | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.35); catalogued as rs760936782, COSV68311661, COSV68314277; called by muse, varscan2
- OBP2A | c.145G>A p.V49M | Missense Mutation (SNP) | VAF 86/316 reads (27%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.869); catalogued as rs755332106; called by muse, mutect2, varscan2
- OBSCN | c.14993C>T p.S4998F | Missense Mutation (SNP) | VAF 379/525 reads (72%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs915552522, COSV52827378; called by muse, mutect2, varscan2
- OPLAH | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 100/549 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs782539103; called by muse, mutect2, varscan2
- OR10A5 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 126/234 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV55053241; called by muse, mutect2, varscan2
- OR11H1 | c.203G>A p.G68E | Missense Mutation (SNP) | VAF 124/657 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); catalogued as COSV99421539; called by muse, mutect2, varscan2
- OR4A47 | c.227C>T p.S76F | Missense Mutation (SNP) | VAF 172/315 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs374887866, COSV71444833; called by muse, mutect2, varscan2
- OR4C13 | c.876G>A p.M292I | Missense Mutation (SNP) | VAF 83/151 reads (55%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.013); catalogued as COSV73648600; called by muse, mutect2, varscan2
- OR4K1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 142/227 reads (63%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs149331048, COSV53458632, COSV53459042; called by muse, mutect2, varscan2
- OR4Q3 | c.921G>A p.M307I | Missense Mutation (SNP) | VAF 164/246 reads (67%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100057056, COSV59180444; called by muse, mutect2, varscan2
- OR52E8 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 167/301 reads (55%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.555); catalogued as rs184389518; called by muse, mutect2, varscan2
- OR5K3 | c.58C>T p.H20Y | Missense Mutation (SNP) | VAF 36/376 reads (10%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as rs1181946996, COSV67350001; called by muse, mutect2
- OR5K4 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 33/243 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.327); catalogued as COSV61584429; called by muse, mutect2, varscan2
- OR5M11 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 68/229 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.192); catalogued as rs1210115062; called by muse, mutect2, varscan2
- OR7G2 | c.835G>A p.V279M | Missense Mutation (SNP) | VAF 65/385 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.26); catalogued as rs747412821, COSV59687579; called by muse, mutect2
- OTC | c.68G>A p.R23Q | Missense Mutation (SNP) | VAF 63/154 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as rs148660170; called by muse, mutect2, varscan2
- OTOGL | c.3388C>T p.P1130S (on ENST00000547103; = p.P1121S on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 73/241 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.779); catalogued as COSV101509062; called by muse, mutect2, varscan2
- P2RX1 | c.734C>T p.T245I | Missense Mutation (SNP) | VAF 61/199 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.224); catalogued as rs1235118152, COSV56654543; called by muse, mutect2, varscan2
- PABPN1L | c.190G>A p.D64N | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); catalogued as rs758693422; called by muse, mutect2, varscan2
- PAK5 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 119/356 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.177); catalogued as rs924744761, COSV62025010; called by muse, mutect2, varscan2
- PARP11 | c.736C>T p.R246C | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.736); catalogued as rs866467165; called by muse, mutect2, varscan2
- PATJ | c.3667G>A p.D1223N | Missense Mutation (SNP) | VAF 48/313 reads (15%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs936211682, COSV57166128, COSV57172287; called by muse, mutect2, varscan2
- PCDH15 | c.2290C>T p.R764C | Missense Mutation (SNP) | VAF 82/286 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as rs192813057, COSV57279849; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDH18 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 51/255 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.845); catalogued as COSV61266439; called by muse, mutect2, varscan2
- PCDH8 | c.1127C>T p.A376V | Missense Mutation (SNP) | VAF 104/536 reads (19%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.056); catalogued as rs1419371240; called by mutect2, varscan2
- PCDHA11 | c.806G>A p.R269Q | Missense Mutation (SNP) | VAF 78/299 reads (26%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); catalogued as rs781996593, COSV56502100; called by muse, mutect2, varscan2
- PCDHB12 | c.865C>T p.R289C | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.02); catalogued as COSV53392799; called by muse, mutect2, varscan2
- PCDHGA1 | c.409G>A p.E137K | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.077); catalogued as rs1330562926; called by muse, mutect2, varscan2
- PCDHGA2 | c.1339G>A p.D447N | Missense Mutation (SNP) | VAF 72/385 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1236347176; called by muse, mutect2, varscan2
- PCDHGB5 | c.2141C>T p.S714F | Missense Mutation (SNP) | VAF 205/311 reads (66%) | SIFT tolerated (0.11); PolyPhen benign (0.111); catalogued as rs976476082; called by muse, mutect2, varscan2
- PDCD1LG2 | c.580T>C p.F194L | Missense Mutation (SNP) | VAF 94/385 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.693); catalogued as rs1247219316; called by muse, mutect2, varscan2
- PDE10A | c.1918G>A p.G640R | Missense Mutation (SNP) | VAF 77/270 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.914); catalogued as COSV63104006; called by muse, mutect2, varscan2
- PDE4DIP | c.4768C>T p.R1590W | Missense Mutation (SNP) | VAF 194/574 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs587673399; called by muse, mutect2, varscan2
- PEG3 | c.4213G>A p.E1405K | Missense Mutation (SNP) | VAF 140/695 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.452); catalogued as rs1343303675, COSV55630571; called by muse, mutect2, varscan2
- PGAP4 | c.206G>A p.S69N | Missense Mutation (SNP) | VAF 96/284 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs867351890; called by muse, mutect2, varscan2
- PGR | c.1909C>T p.R637* | Nonsense Mutation (SNP) | VAF 30/111 reads (27%) | catalogued as rs1209629034, COSV54798528, COSV54801881; called by muse, mutect2, varscan2
- PIP | c.181G>A p.E61K | Missense Mutation (SNP) | VAF 58/368 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs1303868602, COSV52120810; called by muse, mutect2, varscan2
- PLA2G7 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 62/361 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51260255; called by muse, mutect2, varscan2
- PLK5 | c.877G>A p.G293S | Missense Mutation (SNP) | VAF 183/430 reads (43%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as rs1024956170; called by muse, mutect2, varscan2
- PLPPR3 | c.1330G>A p.E444K (on ENST00000520876 / NM_001270366.2; = p.E472K on NM_024888.2) | Missense Mutation (SNP) | VAF 106/545 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.366); catalogued as rs778872745; called by muse, mutect2, varscan2
- PLXNA4 | c.5284C>T p.H1762Y | Missense Mutation (SNP) | VAF 57/434 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.443); catalogued as COSV58147565; called by muse, mutect2, varscan2
- PLXNA4 | c.3688C>T p.P1230S | Missense Mutation (SNP) | VAF 91/509 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771687932, COSV58159355; called by muse, mutect2, varscan2
- PLXNC1 | c.2590C>T p.Q864* | Nonsense Mutation (SNP) | VAF 91/153 reads (59%) | catalogued as COSV51571014; called by muse, varscan2
- PLXND1 | c.4595C>T p.A1532V | Missense Mutation (SNP) | VAF 81/396 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.259); catalogued as rs765431674; called by muse, mutect2, varscan2
- PNMA8B | c.371C>T p.P124L | Missense Mutation (SNP) | VAF 103/568 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.025); catalogued as rs1448994817; called by muse, mutect2, varscan2
- POM121 | c.1763C>T p.S588F (on ENST00000434423; = p.S323F on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/398 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.123); catalogued as COSV99989198; called by muse, mutect2, varscan2
- POM121L12 | c.725C>T p.P242L | Missense Mutation (SNP) | VAF 98/639 reads (15%) | SIFT tolerated (0.67); PolyPhen benign (0.242); catalogued as COSV68692550; called by muse, mutect2, varscan2
- POTEB3 | c.337G>A p.G113S | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.937); catalogued as rs1400384731; called by muse, mutect2, varscan2
- PPEF2 | c.2083G>A p.D695N | Missense Mutation (SNP) | VAF 73/326 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.722); catalogued as rs1228199965; called by muse, mutect2, varscan2
- PREX2 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 33/198 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201372935, COSV99906079; called by muse, mutect2, varscan2
- PRKAA2 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 193/371 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.092); catalogued as COSV64803832; called by muse, mutect2, varscan2
- PRKAA2 | c.1078C>T p.P360S | Missense Mutation (SNP) | VAF 82/443 reads (19%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs1211439926, COSV64802473; called by muse, mutect2, varscan2
- PROKR2 | c.212A>G p.N71S | Missense Mutation (SNP) | VAF 122/325 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775950405, COSV54086060; called by muse, mutect2, varscan2
- PRSS37 | c.482G>A p.R161Q | Missense Mutation (SNP) | VAF 74/458 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs370113489; called by muse, mutect2, varscan2
- PRUNE2 | c.598C>T p.P200S | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65029552; called by muse, mutect2, varscan2
- PSD4 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 82/374 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs771922517; called by muse, mutect2, varscan2
- PSG4 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 68/390 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs540660899, COSV54939642; called by muse, mutect2, varscan2
- PTGDR | c.1066G>A p.E356K | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.056); catalogued as COSV60094472; called by muse, mutect2, varscan2
- PTGER4 | c.1222G>A p.G408S | Missense Mutation (SNP) | VAF 89/377 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs1347713640, COSV100201570; called by muse, mutect2, varscan2
- PTPRD | c.4775G>A p.R1592K | Missense Mutation (SNP) | VAF 96/396 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61943529; called by muse, mutect2, varscan2
- R3HDML | c.565A>G p.S189G | Missense Mutation (SNP) | VAF 80/595 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.192); catalogued as rs750818385; called by muse, mutect2, varscan2
- RALYL | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 151/322 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV72822973; called by muse, mutect2, varscan2
- RANBP3L | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 58/243 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.922); catalogued as COSV56954444, COSV56955268; called by muse, mutect2, varscan2
- RASAL3 | c.202C>T p.R68C | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52992195; called by muse, mutect2, varscan2
- RASL12 | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 82/263 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.12); catalogued as rs572627378; called by muse, mutect2, varscan2
- RASSF6 | c.437G>A p.R146K (on ENST00000342081 / NM_201431.2; = p.R114K on NM_177532.5) | Missense Mutation (SNP) | VAF 51/236 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs780582863, COSV100275034, COSV56717427; called by muse, mutect2, varscan2
- RBM48 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 53/373 reads (14%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as COSV99720092; called by muse, mutect2, varscan2
- REXO5 | c.1633C>T p.L545F | Missense Mutation (SNP) | VAF 48/520 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0.027); catalogued as rs770307551; called by muse, mutect2
- RGPD4 | c.1714C>T p.Q572* | Nonsense Mutation (SNP) | VAF 52/343 reads (15%) | catalogued as COSV100736435; called by muse, mutect2, varscan2
- RIC3 | c.911C>T p.S304F (on ENST00000309737 / NM_001206671.4; = p.S303F on NM_024557.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.242); catalogued as rs761134805; called by muse, mutect2, varscan2
- RNF113B | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 42/237 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.091); catalogued as COSV57434708; called by muse, mutect2, varscan2
- RNF180 | c.34C>T p.H12Y | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs377421270; called by muse, mutect2, varscan2
- RP1 | c.3134C>T p.S1045L | Missense Mutation (SNP) | VAF 52/330 reads (16%) | SIFT tolerated (0.36); PolyPhen benign (0.007); catalogued as COSV55116794; called by muse, mutect2, varscan2
- RP1 | c.4261G>A p.E1421K | Missense Mutation (SNP) | VAF 154/303 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55116321; called by muse, mutect2, varscan2
- RP1L1 | c.5012C>T p.S1671F | Missense Mutation (SNP) | VAF 73/488 reads (15%) | SIFT tolerated (0.16); PolyPhen benign (0.055); catalogued as rs1056208866; called by muse, mutect2, varscan2
- RP1L1 | c.3833G>A p.R1278K | Missense Mutation (SNP) | VAF 94/474 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV101223015; called by muse, mutect2, varscan2
- RTL3 | c.1231G>A p.G411R | Missense Mutation (SNP) | VAF 190/275 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as rs1439203118; called by muse, mutect2, varscan2
- RUBCNL | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 43/257 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.048); catalogued as rs868237776; called by muse, mutect2, varscan2
- RYR1 | c.2059C>T p.L687F | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.919); catalogued as rs1296515481; called by muse, mutect2, varscan2
- RYR1 | c.4310G>A p.R1437K | Missense Mutation (SNP) | VAF 91/278 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs1568474736, COSV62093592; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SALL1 | c.2960G>A p.G987E | Missense Mutation (SNP) | VAF 55/249 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.356); catalogued as COSV99175169; called by muse, mutect2, varscan2
- SAP30BP | c.196G>A p.D66N | Missense Mutation (SNP) | VAF 65/440 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs1433224866; called by muse, mutect2, varscan2
- SAT1 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 182/236 reads (77%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.59); catalogued as COSV100803871; called by muse, mutect2, varscan2
- SCN5A | c.4773G>A p.W1591* (on ENST00000333535 / NM_198056.3; = p.W1590* on NM_000335.5) | Nonsense Mutation (SNP) | VAF 60/270 reads (22%) | catalogued as rs868097890, CM100743, COSV100346871; called by muse, mutect2, varscan2
- SCN5A | c.1291G>A p.E431K | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV61114841; called by muse, mutect2, varscan2
- SCN7A | c.1656G>A p.M552I | Missense Mutation (SNP) | VAF 46/177 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.266); catalogued as rs1375068867, COSV69272914; called by muse, mutect2, varscan2
- SCN9A | c.5614C>T p.P1872S (on ENST00000303354; = p.P1861S on NM_002977.3) | Missense Mutation (SNP) | VAF 37/291 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV57602094; called by muse, mutect2, varscan2
- SEMA3A | c.2207G>A p.R736K | Missense Mutation (SNP) | VAF 64/449 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54884255; called by muse, mutect2, varscan2
- SERPINA12 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 241/334 reads (72%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as rs200162086, COSV57944055; called by muse, mutect2, varscan2
- SERPINA7 | c.392G>A p.G131E | Missense Mutation (SNP) | VAF 92/168 reads (55%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs148370308, COSV59666422; called by muse, mutect2, varscan2
- SERPINB10 | c.631G>A p.E211K | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs539628633; called by muse, varscan2
- SERPINB11 | c.223C>T p.P75S | Missense Mutation (SNP) | VAF 45/243 reads (19%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as rs1568184442; called by muse, mutect2, varscan2
- SERPINB11 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 46/241 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1240493765; called by muse, mutect2, varscan2
- SERPINB13 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.899); catalogued as rs753363525, COSV99501225; called by muse, mutect2, varscan2
- SETD2 | c.2030C>T p.P677L | Missense Mutation (SNP) | VAF 145/315 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.563); catalogued as rs766229574; called by muse, mutect2, varscan2
- SETD2 | c.2029C>T p.P677S | Missense Mutation (SNP) | VAF 145/316 reads (46%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.048); catalogued as rs764219907, COSV57433582, COSV57436586; ClinVar: benign; called by muse, mutect2, varscan2
- SH2D1B | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 71/280 reads (25%) | SIFT tolerated (0.78); PolyPhen benign (0.069); catalogued as rs774783057, COSV63391995; called by muse, mutect2, varscan2
- SIGLEC14 | c.605C>T p.P202L | Missense Mutation (SNP) | VAF 187/612 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as rs1308140616, COSV99707805; called by muse, mutect2, varscan2
- SIGLEC9 | c.1361G>A p.W454* | Nonsense Mutation (SNP) | VAF 82/449 reads (18%) | catalogued as rs1247435799; called by muse, mutect2, varscan2
- SLC25A20 | c.431C>T p.S144L | Missense Mutation (SNP) | VAF 92/210 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as rs962783525; called by muse, mutect2, varscan2
- SLC25A40 | c.193C>T p.H65Y | Missense Mutation (SNP) | VAF 40/374 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1403951544; called by muse, mutect2, varscan2
- SLC2A6 | c.496C>T p.R166C | Missense Mutation (SNP) | VAF 88/312 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs892330468, COSV64143156; called by muse, mutect2, varscan2
- SLC35B2 | c.491T>C p.L164P | Missense Mutation (SNP) | VAF 51/434 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1411592482, COSV51488664; called by muse, mutect2, varscan2
- SLC38A10 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 65/508 reads (13%) | SIFT tolerated (0.46); PolyPhen benign (0.014); catalogued as COSV55844135; called by muse, mutect2, varscan2
- SLC4A10 | c.1228C>T p.R410C (on ENST00000446997 / NM_001354461.2; = p.R380C on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 42/231 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs558073659, COSV55769372; called by muse, mutect2, varscan2
- SLC4A11 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.071); catalogued as rs375415674; called by muse, mutect2, varscan2
- SLC4A5 | c.3386G>A p.R1129K | Missense Mutation (SNP) | VAF 69/269 reads (26%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.413); catalogued as rs748093809; called by muse, mutect2, varscan2
- SLC5A10 | c.1394G>A p.R465Q (on ENST00000395645 / NM_001042450.4; = p.R481Q on NM_152351.5) | Missense Mutation (SNP) | VAF 67/342 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.006); catalogued as rs762789917; called by muse, mutect2, varscan2
- SLC5A7 | c.1432C>T p.P478S | Missense Mutation (SNP) | VAF 64/324 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50890843; called by muse, mutect2, varscan2
- SLCO1B3 | c.392C>T p.P131L | Missense Mutation (SNP) | VAF 19/111 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.038); catalogued as rs868695861; called by muse, mutect2, varscan2
- SLCO2A1 | c.1798G>A p.D600N | Missense Mutation (SNP) | VAF 61/281 reads (22%) | SIFT tolerated (0.29); PolyPhen benign (0.034); catalogued as rs762008407, COSV60488280; called by muse, mutect2, varscan2
- SLX4 | c.1654C>T p.P552S | Missense Mutation (SNP) | VAF 79/445 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53561174; called by muse, mutect2, varscan2
- SORCS2 | c.2581G>A p.D861N | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.569); catalogued as rs377586569; called by muse, mutect2, varscan2
- SORCS3 | c.1252C>T p.R418* | Nonsense Mutation (SNP) | VAF 70/230 reads (30%) | catalogued as rs371068614, COSV63810890; called by muse, mutect2, varscan2
- SP140 | c.1478G>A p.G493E | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.672); catalogued as COSV59455634; called by muse, mutect2, varscan2
- SPAM1 | c.172G>A p.E58K | Missense Mutation (SNP) | VAF 89/570 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs779755476, COSV56141188; called by muse, mutect2, varscan2
- SPOCK1 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 35/261 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs267600350, COSV56458405; called by muse, mutect2, varscan2
- SRRM5 | c.1244G>A p.R415Q | Missense Mutation (SNP) | VAF 117/764 reads (15%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as rs1157131508; called by muse, mutect2, varscan2
- STAG1 | c.346G>A p.A116T | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.271); catalogued as rs757393709, COSV52600654; called by muse, mutect2, varscan2
- STK39 | c.595C>T p.L199F | Missense Mutation (SNP) | VAF 91/212 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63597465, COSV63599628; called by muse, mutect2, varscan2
- STRBP | c.1124G>A p.R375Q | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.034); catalogued as rs767462142, COSV62117307; called by muse, mutect2, varscan2
- SVEP1 | c.8470G>A p.D2824N | Missense Mutation (SNP) | VAF 82/277 reads (30%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs758634901; called by muse, mutect2, varscan2
- SVOPL | c.616C>T p.R206C (on ENST00000419765; = p.R54C on NM_174959.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 142/464 reads (31%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.986); catalogued as rs143755972; called by muse, mutect2, varscan2
- SYNM | c.1427G>A p.R476Q | Missense Mutation (SNP) | VAF 97/305 reads (32%) | SIFT tolerated (0.32); PolyPhen benign (0.02); catalogued as rs782352571; called by muse, mutect2, varscan2
- TBC1D5 | c.1823A>G p.Y608C | Missense Mutation (SNP) | VAF 33/199 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99509282; called by muse, mutect2, varscan2
- TECPR1 | c.1457C>T p.P486L | Missense Mutation (SNP) | VAF 84/522 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.03); catalogued as COSV65784409; called by muse, varscan2
- TENM1 | c.3058C>T p.P1020S | Missense Mutation (SNP) | VAF 54/94 reads (57%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.985); catalogued as COSV100950431; called by muse, mutect2, varscan2
- TESPA1 | c.815G>A p.R272Q (on ENST00000316577 / NM_001098815.3; = p.R134Q on NM_014796.2 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 74/332 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as rs371796001; called by muse, mutect2, varscan2
- TET2 | c.5750G>A p.W1917* | Nonsense Mutation (SNP) | VAF 87/369 reads (24%) | catalogued as COSV54425719; called by muse, mutect2, varscan2
- TFAP2B | c.218C>T p.P73L | Missense Mutation (SNP) | VAF 102/547 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.055); catalogued as CM014600, COSV53829756; called by muse, mutect2, varscan2
- TGM7 | c.515G>A p.G172D | Missense Mutation (SNP) | VAF 68/212 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1043666538; called by muse, mutect2, varscan2
- THBS1 | c.1825G>A p.E609K | Missense Mutation (SNP) | VAF 81/258 reads (31%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as rs746472820, COSV52955714; called by muse, mutect2, varscan2
- THBS2 | c.1603G>A p.G535R | Missense Mutation (SNP) | VAF 56/233 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as rs1485386556; called by muse, mutect2, varscan2
- TLE3 | c.2125G>T p.A709S | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as rs370776098, COSV58170421; called by muse, mutect2
- TMED3 | c.421C>T p.P141S | Missense Mutation (SNP) | VAF 98/346 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1464497670; called by muse, mutect2
- TMEM145 | c.421G>A p.G141S | Missense Mutation (SNP) | VAF 120/435 reads (28%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.867); catalogued as rs1337229668; called by muse, mutect2, varscan2
- TNRC6C | c.4076C>T p.P1359L | Missense Mutation (SNP) | VAF 258/616 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as rs1250963505, COSV100050390, COSV56947454; called by muse, mutect2
- TRIM29 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 77/330 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.133); catalogued as COSV100532091; called by muse, mutect2, varscan2
- TRPC4 | c.62G>A p.R21K | Missense Mutation (SNP) | VAF 45/347 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.387); catalogued as COSV100156686; called by muse, mutect2, varscan2
- TRPM2 | c.4402G>A p.D1468N | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs145895219; called by muse, mutect2, varscan2
- TRPM7 | c.3221C>T p.P1074L | Missense Mutation (SNP) | VAF 36/143 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as COSV57914692; called by muse, mutect2, varscan2
- TSHZ2 | c.2971G>A p.D991N | Missense Mutation (SNP) | VAF 77/527 reads (15%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); catalogued as COSV61590310; called by muse, mutect2, varscan2
- TSPAN6 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV65957406; called by muse, mutect2
- TTN | c.47390G>A p.G15797E (on ENST00000591111; = p.G8373E on NM_003319.4) | Missense Mutation (SNP) | VAF 92/316 reads (29%) | PolyPhen benign (0.006); catalogued as rs1356720044, COSV59883740, COSV59927186; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.38497G>A p.E12833K (on ENST00000591111; = p.E5409K on NM_003319.4) | Missense Mutation (SNP) | VAF 41/290 reads (14%) | PolyPhen probably damaging (0.994); catalogued as COSV60441186; called by muse, mutect2, varscan2
- TTN | c.35044G>A p.E11682K (on ENST00000591111; = p.E10755K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/171 reads (24%) | PolyPhen benign (0.003); catalogued as COSV60082234; called by muse, mutect2, varscan2
- TTN | c.31301C>T p.S10434L (on ENST00000591111; = p.S9507L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/346 reads (18%) | PolyPhen probably damaging (0.943); catalogued as COSV60253144; called by muse, mutect2, varscan2
- TTN | c.31048C>T p.P10350S (on ENST00000591111; = p.P9423S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 122/265 reads (46%) | PolyPhen benign (0.272); catalogued as rs1560404396; called by muse, mutect2, varscan2
- TTN | c.908C>T p.P303L | Missense Mutation (SNP) | VAF 104/207 reads (50%) | PolyPhen probably damaging (0.999); catalogued as rs760653342, COSV59886963; called by muse, mutect2, varscan2
- TUBA3C | c.962G>A p.G321E | Missense Mutation (SNP) | VAF 99/572 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV68028632; called by muse, mutect2, varscan2
- TXNDC2 | c.1201G>A p.E401K (on ENST00000306084 / NM_001098529.2; = p.E334K on NM_032243.6) | Missense Mutation (SNP) | VAF 110/369 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.091); catalogued as rs144825639; called by muse, mutect2, varscan2
- UBTF | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 129/330 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776388682; called by muse, mutect2, varscan2
- UBXN7 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 77/201 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV56358298; called by muse, mutect2, varscan2
- UGT3A2 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 28/159 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1170089841; called by muse, mutect2, varscan2
- ULK3 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 82/316 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs1402261743, COSV51513212; called by muse, mutect2, varscan2
- UNC80 | c.3221C>T p.S1074F | Missense Mutation (SNP) | VAF 74/391 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55886364; called by muse, mutect2, varscan2
- USP17L17 | c.70C>T p.R24W | Missense Mutation (SNP) | VAF 86/1588 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1163212918; called by muse, mutect2
- USP6 | c.1010C>T p.T337I | Missense Mutation (SNP) | VAF 111/203 reads (55%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.007); catalogued as COSV100002822; called by muse, mutect2, varscan2
- VCAN | c.4904C>T p.S1635L | Missense Mutation (SNP) | VAF 93/376 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.091); catalogued as rs773159382, COSV54095992, COSV54105899; called by muse, mutect2, varscan2
- VWA8 | c.2725C>T p.P909S | Missense Mutation (SNP) | VAF 124/252 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55705277; called by muse, mutect2, varscan2
- WDFY4 | c.5744G>A p.R1915Q | Missense Mutation (SNP) | VAF 58/226 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.072); catalogued as rs1410306140; called by muse, mutect2, varscan2
- WDR35 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs775925668, COSV55604803; called by muse, mutect2, varscan2
- ZAN | c.2158C>T p.P720S | Missense Mutation (SNP) | VAF 102/566 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.882); catalogued as rs573121604, COSV61809864; called by mutect2, varscan2
- ZCWPW1 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 141/345 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.52); catalogued as rs1171403919; called by muse, mutect2, varscan2
- ZFHX4 | c.4615C>T p.R1539C | Missense Mutation (SNP) | VAF 146/451 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779791348, COSV51462677; called by muse, mutect2, varscan2
- ZFPM2 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 70/399 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.968); catalogued as rs752577785, COSV68278632; called by muse, mutect2, varscan2
- ZIK1 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 71/407 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0.15); catalogued as COSV56736727; called by muse, mutect2, varscan2
- ZNF318 | c.1054C>T p.P352S | Missense Mutation (SNP) | VAF 166/459 reads (36%) | SIFT tolerated (0.11); PolyPhen benign (0.301); catalogued as COSV58930740; called by muse, mutect2, varscan2
- ZNF366 | c.1864G>A p.E622K | Missense Mutation (SNP) | VAF 96/487 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs938845953; called by muse, mutect2, varscan2
- ZNF385B | c.1423C>T p.R475C | Missense Mutation (SNP) | VAF 79/426 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs572842673, COSV61182308; called by muse, mutect2, varscan2
- ZNF423 | c.3411T>A p.F1137L (on ENST00000563137 / NM_001379286.1; = p.F1129L on NM_015069.4) | Missense Mutation (SNP) | VAF 189/329 reads (57%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.823); catalogued as rs1399280195; called by muse, mutect2, varscan2
- ZNF430 | c.638C>T p.S213L | Missense Mutation (SNP) | VAF 84/210 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.277); catalogued as rs776882876, COSV55109946; called by muse, mutect2, varscan2
- ZNF432 | c.1582C>T p.L528F | Missense Mutation (SNP) | VAF 181/562 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1032188069; called by muse, mutect2, varscan2
- ZNF536 | c.1795G>A p.D599N | Missense Mutation (SNP) | VAF 149/409 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.157); catalogued as rs748156582, COSV62833857; called by muse, mutect2, varscan2
- ZNF574 | c.1219C>T p.L407F | Missense Mutation (SNP) | VAF 86/497 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV55902198; called by muse, mutect2, varscan2
- ZNF582 | c.1165C>T p.H389Y | Missense Mutation (SNP) | VAF 155/470 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV56733873; called by muse, mutect2, varscan2
- ZNF69 | c.1328C>T p.P443L | Missense Mutation (SNP) | VAF 50/252 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV60903474; called by muse, mutect2, varscan2
- ZNF705G | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 56/656 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.903); catalogued as rs1467477261, COSV67950374; called by muse, mutect2
- ZNF711 | c.685G>A p.G229S | Missense Mutation (SNP) | VAF 74/216 reads (34%) | SIFT tolerated (0.84); PolyPhen benign (0.028); catalogued as COSV52158532; called by muse, mutect2, varscan2
- ZNF804A | c.2441G>A p.R814Q | Missense Mutation (SNP) | VAF 140/320 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs765819874, COSV56437566; called by muse, mutect2, varscan2
- ZNF813 | c.589C>T p.R197W | Missense Mutation (SNP) | VAF 48/320 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1285563398, COSV67176200; called by muse, mutect2, varscan2
- ZNF835 | c.239C>T p.S80F | Missense Mutation (SNP) | VAF 177/499 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV101606322, COSV104440719; called by muse, mutect2, varscan2
- ZPLD1 | c.839G>A p.R280Q (on ENST00000466937 / NM_001329788.1; = p.R296Q on NM_175056.2) | Missense Mutation (SNP) | VAF 143/328 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770785388, COSV100082810, COSV60353683; called by muse, varscan2
- ZSWIM2 | c.1862G>A p.S621N | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV54574713; called by muse, mutect2, varscan2
- ABCA13 | c.13658G>A p.W4553* | Nonsense Mutation (SNP) | VAF 117/362 reads (32%) | called by muse, mutect2, varscan2
- ABCC2 | c.1718T>C p.I573T | Missense Mutation (SNP) | VAF 16/356 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.864); called by muse, mutect2
- ACSM2A | c.493C>T p.Q165* (on ENST00000219054; = p.Q86* on NM_001308169.2) | Nonsense Mutation (SNP) | VAF 107/330 reads (32%) | called by muse, mutect2, varscan2
- ACTR3C | c.254G>A p.G85E | Missense Mutation (SNP) | VAF 49/383 reads (13%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ADAM22 | c.952G>A p.D318N | Missense Mutation (SNP) | VAF 239/546 reads (44%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ADAMTS10 | c.2329C>T p.Q777* | Nonsense Mutation (SNP) | VAF 68/435 reads (16%) | called by muse, mutect2, varscan2
- ADAMTS15 | c.2299G>A p.E767K | Missense Mutation (SNP) | VAF 96/344 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADD2 | c.1117G>A p.D373N | Missense Mutation (SNP) | VAF 52/282 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRG6 | c.2531G>A p.G844E | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADPRHL1 | c.1330T>G p.Y444D | Missense Mutation (SNP) | VAF 209/434 reads (48%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.74); called by muse, mutect2, varscan2
- AGO3 | c.2371T>C p.Y791H | Missense Mutation (SNP) | VAF 201/368 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- AKAP13 | c.7081_7087+10del p.X2361_splice (on ENST00000394518 / NM_007200.5; = p.X2365_splice on NM_006738.6) | Splice Site (DEL) | VAF 24/224 reads (11%) | called by mutect2, pindel
- AL441992.2 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 79/301 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALDH1L1 | c.827G>A p.G276E | Missense Mutation (SNP) | VAF 81/313 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALMS1 | c.10204G>A p.D3402N | Missense Mutation (SNP) | VAF 87/218 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ANGPTL2 | c.910C>A p.Q304K | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.679); called by muse, varscan2
- ANK1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 39/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- ANK3 | c.2968G>A p.V990M (on ENST00000280772 / NM_001320874.2; = p.V124M on NM_001149.3) | Missense Mutation (SNP) | VAF 57/187 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- ANKHD1-EIF4EBP3 | c.4105G>A p.G1369S | Missense Mutation (SNP) | VAF 25/139 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD12 | c.947C>T p.S316F | Missense Mutation (SNP) | VAF 29/90 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.624); called by muse, mutect2, varscan2
- ANKRD30B | c.2731G>A p.E911K | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.486); called by muse, mutect2
- ANKRD31 | c.5477G>A p.G1826E | Missense Mutation (SNP) | VAF 94/185 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- ANPEP | c.2081C>T p.P694L | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ANTXR1 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 42/209 reads (20%) | SIFT tolerated, low confidence (0.66); PolyPhen possibly damaging (0.57); called by muse, mutect2, varscan2
- APBA1 | c.2179A>C p.K727Q | Missense Mutation (SNP) | VAF 42/100 reads (42%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.984); called by muse, varscan2
- APC2 | c.571G>A p.A191T | Missense Mutation (SNP) | VAF 101/371 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, varscan2
- APOC2 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 143/431 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- AQP1 | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 58/515 reads (11%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGAP25 | c.238G>A p.D80N (on ENST00000409202 / NM_001007231.3; = p.D73N on NM_014882.3) | Missense Mutation (SNP) | VAF 49/275 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ARHGAP35 | c.2306G>C p.S769T | Missense Mutation (SNP) | VAF 166/435 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ARID5A | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 101/512 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ARMH3 | c.1634C>T p.P545L | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- ASB18 | c.794G>A p.R265K | Missense Mutation (SNP) | VAF 31/203 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ATAD5 | c.2135C>T p.A712V | Missense Mutation (SNP) | VAF 57/306 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- ATF7IP2 | c.982G>A p.E328K | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ATP13A4 | c.1204C>T p.L402F | Missense Mutation (SNP) | VAF 77/354 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- ATP2A2 | c.478C>T p.P160S | Missense Mutation (SNP) | VAF 61/193 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ATP6V0A4 | c.1376C>T p.S459F | Missense Mutation (SNP) | VAF 57/539 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP8A1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 61/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- AVPR1A | c.437C>A p.T146K | Missense Mutation (SNP) | VAF 177/297 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- B4GALT4 | c.701G>A p.G234D | Missense Mutation (SNP) | VAF 97/282 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BBS2 | c.727C>T p.H243Y | Missense Mutation (SNP) | VAF 66/121 reads (55%) | SIFT tolerated (0.82); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- BCAS1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 235/362 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BCL9 | c.2030T>C p.F677S | Missense Mutation (SNP) | VAF 262/617 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- BMP15 | c.553G>C p.D185H | Missense Mutation (SNP) | VAF 49/160 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- C10orf71 | c.3071G>A p.W1024* | Nonsense Mutation (SNP) | VAF 90/329 reads (27%) | called by muse, mutect2, varscan2
- C4A | c.3437C>T p.T1146I | Missense Mutation (SNP) | VAF 37/316 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- C6orf15 | c.571C>T p.L191F | Missense Mutation (SNP) | VAF 304/760 reads (40%) | SIFT tolerated (0.32); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- C9 | c.896G>A p.G299E | Missense Mutation (SNP) | VAF 70/224 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- CAB39L | c.1006G>A p.A336T | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- CAB39L | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 147/328 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CACNA1B | c.5125G>A p.D1709N | Missense Mutation (SNP) | VAF 70/206 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CAMSAP3 | c.1750G>A p.G584R | Missense Mutation (SNP) | VAF 86/368 reads (23%) | SIFT tolerated (0.47); PolyPhen benign (0.152); called by muse, mutect2, varscan2
- CCDC168 | c.10301C>T p.S3434L | Missense Mutation (SNP) | VAF 52/293 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- CCDC197 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 121/197 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CDH2 | c.2602G>A p.G868R | Missense Mutation (SNP) | VAF 68/295 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CDH5 | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 225/397 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- CDHR4 | c.1486G>A p.E496K | Missense Mutation (SNP) | VAF 55/266 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CELSR2 | c.1943_1948del p.T648_G650delinsS | In Frame Del (DEL) | VAF 50/399 reads (13%) | called by mutect2, pindel, varscan2
- CEP104 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 202/330 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.689); called by muse, mutect2, varscan2
- CFAP47 | c.2777C>T p.P926L | Missense Mutation (SNP) | VAF 141/191 reads (74%) | SIFT deleterious (0.01); PolyPhen benign (0.211); called by muse, mutect2, varscan2
- CFHR1 | c.808C>T p.R270* | Nonsense Mutation (SNP) | VAF 244/330 reads (74%) | called by muse, mutect2, varscan2
- CHD6 | c.7562T>C p.M2521T | Missense Mutation (SNP) | VAF 87/483 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- CLGN | c.1442G>A p.G481E | Missense Mutation (SNP) | VAF 57/291 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- CLGN | c.752G>A p.G251E | Missense Mutation (SNP) | VAF 71/299 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLYBL | c.35G>A p.G12E | Missense Mutation (SNP) | VAF 156/325 reads (48%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- CNGB3 | c.1136G>A p.G379E | Missense Mutation (SNP) | VAF 105/213 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL15A1 | c.2344G>A p.G782R | Missense Mutation (SNP) | VAF 54/211 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- COL16A1 | c.1961C>T p.P654L | Missense Mutation (SNP) | VAF 174/504 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL19A1 | c.1747G>A p.G583R | Missense Mutation (SNP) | VAF 92/346 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, varscan2
- COL22A1 | c.4003C>T p.P1335S | Missense Mutation (SNP) | VAF 161/464 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- CPED1 | c.2174G>A p.G725D | Missense Mutation (SNP) | VAF 163/357 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CRB2 | c.2269C>T p.Q757* | Nonsense Mutation (SNP) | VAF 107/392 reads (27%) | called by muse, mutect2, varscan2
- CRYBG3 | c.8128T>A p.Y2710N | Missense Mutation (SNP) | VAF 49/189 reads (26%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- CRYGN | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 39/261 reads (15%) | SIFT tolerated (0.84); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CSE1L | c.785G>A p.G262D | Missense Mutation (SNP) | VAF 207/322 reads (64%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CSTA | c.169-1G>A p.X57_splice | Splice Site (SNP) | VAF 81/151 reads (54%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1804G>A p.D602N | Missense Mutation (SNP) | VAF 57/260 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.334); called by muse, mutect2
- CTTNBP2 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 82/529 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CYFIP2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 67/297 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.857); called by muse, varscan2
- CYP21A2 | c.852G>A p.M284I | Missense Mutation (SNP) | VAF 140/777 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CYP2C9 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- CYP4Z1 | c.1429C>T p.P477S | Missense Mutation (SNP) | VAF 71/431 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DCDC1 | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 96/177 reads (54%) | SIFT tolerated (0.1); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DENND2B | c.458C>T p.T153I | Missense Mutation (SNP) | VAF 188/330 reads (57%) | SIFT tolerated (0.07); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- DMP1 | c.1034A>G p.N345S | Missense Mutation (SNP) | VAF 228/365 reads (62%) | SIFT tolerated (0.09); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- DNAH11 | c.2983G>A p.E995K | Missense Mutation (SNP) | VAF 23/330 reads (7%) | SIFT tolerated (0.56); PolyPhen possibly damaging (0.475); called by muse, mutect2
- DNAH12 | c.5818G>A p.D1940N (on ENST00000351747; = p.D1959N on NM_001366028.2) | Missense Mutation (SNP) | VAF 37/228 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DNAH14 | c.6586-1G>A p.X2196_splice (on ENST00000445597; = p.X2849_splice on NM_001367479.1) | Splice Site (SNP) | VAF 60/266 reads (23%) | called by muse, mutect2, varscan2
- DNAH17 | c.9296C>T p.A3099V | Missense Mutation (SNP) | VAF 93/381 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- DNAH17 | c.2585A>C p.Y862S | Missense Mutation (SNP) | VAF 187/410 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- DNAH3 | c.9530G>A p.R3177K | Missense Mutation (SNP) | VAF 75/583 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DNAJC13 | c.4956A>T p.L1652F | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.33); called by muse, mutect2, varscan2
- DNAJC13 | c.4957C>A p.L1653I | Missense Mutation (SNP) | VAF 33/169 reads (20%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- DPYD | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 229/442 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DPYSL5 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 100/211 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DSG3 | c.239C>T p.T80I | Missense Mutation (SNP) | VAF 103/237 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- DUS3L | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 236/565 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- EFEMP1 | c.950C>T p.S317L | Missense Mutation (SNP) | VAF 102/245 reads (42%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); called by muse, varscan2
- EIF2AK3 | c.3094A>T p.T1032S | Missense Mutation (SNP) | VAF 55/143 reads (38%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- EIF2S3B | c.241C>T p.L81F | Missense Mutation (SNP) | VAF 129/242 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- EOLA1 | c.275C>T p.T92I | Missense Mutation (SNP) | VAF 73/185 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); called by muse, mutect2, varscan2
- EPB41L1 | c.745G>A p.E249K | Missense Mutation (SNP) | VAF 62/325 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EXO5 | c.464C>T p.P155L | Missense Mutation (SNP) | VAF 210/378 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- F13A1 | c.2138A>G p.D713G | Missense Mutation (SNP) | VAF 90/444 reads (20%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.797); called by muse, varscan2
- F13A1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 67/315 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FAM126B | c.622T>A p.S208T | Missense Mutation (SNP) | VAF 37/213 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- FAM186B | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 91/280 reads (33%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- FAM3D | c.137A>C p.K46T | Missense Mutation (SNP) | VAF 82/337 reads (24%) | SIFT tolerated (0.47); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FAM71A | c.778C>T p.P260S | Missense Mutation (SNP) | VAF 233/434 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- FAM76A | c.204C>T p.P68= | Splice Region (SNP) | VAF 79/258 reads (31%) | called by muse, mutect2, varscan2
- FANCD2 | c.3013C>T p.Q1005* | Nonsense Mutation (SNP) | VAF 57/254 reads (22%) | called by muse, varscan2
- FAT4 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 306/458 reads (67%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- FBLN5 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 172/306 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FES | c.1231T>C p.S411P | Missense Mutation (SNP) | VAF 67/268 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- FLNC | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 82/537 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.042); called by muse, varscan2
- FPGT-TNNI3K | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 146/314 reads (46%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- FREM1 | c.2237A>T p.D746V | Missense Mutation (SNP) | VAF 202/413 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- FYB2 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 71/398 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GABRR1 | c.911G>A p.W304* | Nonsense Mutation (SNP) | VAF 153/461 reads (33%) | called by muse, mutect2, varscan2
- GALC | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 180/330 reads (55%) | SIFT tolerated (0.79); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GBF1 | c.4099C>T p.P1367S (on ENST00000369983 / NM_001377137.1; = p.P1366S on NM_004193.3) | Missense Mutation (SNP) | VAF 87/261 reads (33%) | SIFT tolerated (0.28); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GMFB | c.17T>C p.V6A | Missense Mutation (SNP) | VAF 45/196 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- GNAZ | c.5G>A p.G2E | Missense Mutation (SNP) | VAF 49/173 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- GOLGA6C | c.744G>A p.W248* | Nonsense Mutation (SNP) | VAF 67/267 reads (25%) | called by muse, mutect2, varscan2
- GOLGA6L2 | c.2707C>T p.P903S | Missense Mutation (SNP) | VAF 49/211 reads (23%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- GOLGA8S | c.220G>A p.D74N | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- GOT1L1 | c.501A>G p.I167M | Missense Mutation (SNP) | VAF 33/219 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- GSTT2B | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by mutect2, varscan2
- HDAC9 | c.2524C>A p.L842I | Missense Mutation (SNP) | VAF 192/435 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.373); called by muse, mutect2, varscan2
- HIRA | c.205C>T p.H69Y | Missense Mutation (SNP) | VAF 44/152 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HIRIP3 | c.94A>G p.R32G | Missense Mutation (SNP) | VAF 81/430 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- HLA-A | c.63G>C p.Q21H | Missense Mutation (SNP) | VAF 166/458 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- HNF1B | c.1310C>T p.P437L | Missense Mutation (SNP) | VAF 104/338 reads (31%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- HNRNPR | c.1534C>T p.P512S | Missense Mutation (SNP) | VAF 267/557 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- HOXC13 | c.101G>A p.G34E | Missense Mutation (SNP) | VAF 117/438 reads (27%) | SIFT tolerated, low confidence (1); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- HTR2C | c.1223G>A p.G408E | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IDO2 | c.727G>A p.D243N (on ENST00000389060; = p.D256N on NM_194294.2) | Missense Mutation (SNP) | VAF 95/287 reads (33%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- IGBP1 | c.828dup p.Y277Ifs*35 | Frame Shift Ins (INS) | VAF 106/232 reads (46%) | called by pindel, varscan2
- IGBP1 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 105/162 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, varscan2
- IGLC3 | c.88A>C p.I30L | Missense Mutation (SNP) | VAF 38/272 reads (14%) | PolyPhen benign (0.129); called by muse, varscan2
- IKZF2 | c.1148C>A p.P383H | Missense Mutation (SNP) | VAF 83/342 reads (24%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IRF2 | c.501T>G p.N167K | Missense Mutation (SNP) | VAF 147/231 reads (64%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITGA2 | c.2430-1G>A p.X810_splice | Splice Site (SNP) | VAF 83/198 reads (42%) | called by muse, mutect2, varscan2
- JAK1 | c.430C>T p.P144S | Missense Mutation (SNP) | VAF 58/362 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- KCNH8 | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 49/282 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KIAA1210 | c.3008C>T p.S1003L | Missense Mutation (SNP) | VAF 96/152 reads (63%) | SIFT tolerated (0.17); PolyPhen benign (0.078); called by muse, mutect2, varscan2
- KIAA1217 | c.511C>T p.P171S | Missense Mutation (SNP) | VAF 67/160 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIAA2012 | c.707G>A p.G236E | Missense Mutation (SNP) | VAF 133/302 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- KIF19 | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 194/391 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- KIF3B | c.956C>T p.P319L | Missense Mutation (SNP) | VAF 193/389 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIR2DL3 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 34/451 reads (8%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.907); called by muse, mutect2
- KLF18 | c.2617G>A p.D873N | Missense Mutation (SNP) | VAF 69/423 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.737); called by muse, mutect2, varscan2
- KLHDC7A | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 99/557 reads (18%) | SIFT tolerated (0.12); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KLHL32 | c.1346G>A p.W449* | Nonsense Mutation (SNP) | VAF 37/171 reads (22%) | called by muse, mutect2, varscan2
- KLHL38 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 107/833 reads (13%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- KLK14 | c.25C>T p.Q9* | Nonsense Mutation (SNP) | VAF 105/309 reads (34%) | called by muse, mutect2, varscan2
- KRT76 | c.107C>T p.S36F | Missense Mutation (SNP) | VAF 104/367 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KRTAP4-7 | c.305C>T p.S102F | Missense Mutation (SNP) | VAF 58/545 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); called by muse, varscan2
- KY | c.1360C>T p.P454S | Missense Mutation (SNP) | VAF 55/336 reads (16%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); called by muse, varscan2
- LAMA2 | c.7124C>T p.A2375V | Missense Mutation (SNP) | VAF 104/163 reads (64%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- LDB2 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 62/289 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHX2 | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 23/161 reads (14%) | SIFT tolerated (0.52); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- LILRA5 | c.318G>A p.M106I | Missense Mutation (SNP) | VAF 113/674 reads (17%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.676); called by muse, mutect2, varscan2
- LIMK1 | c.1313T>C p.V438A | Missense Mutation (SNP) | VAF 186/445 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.18); called by muse, mutect2, varscan2
- LINC02881 | n.373G>T | Splice Region (SNP) | VAF 75/244 reads (31%) | called by muse, mutect2, varscan2
- LRFN1 | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 170/466 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- LRP3 | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 71/365 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.38); called by muse, mutect2, varscan2
- LRPPRC | c.1804G>A p.E602K | Missense Mutation (SNP) | VAF 110/284 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- LRRK1 | c.973G>A p.E325K | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.156); called by muse, mutect2, varscan2
- LTBP2 | c.4013C>T p.P1338L | Missense Mutation (SNP) | VAF 56/246 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LVRN | c.322G>A p.D108N | Missense Mutation (SNP) | VAF 125/411 reads (30%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.521); called by muse, mutect2, varscan2
- LYPD1 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 60/329 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LYZL4 | c.419G>A p.W140* | Nonsense Mutation (SNP) | VAF 66/321 reads (21%) | called by muse, mutect2, varscan2
- MAN2B2 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MANSC4 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 64/302 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.559); called by muse, mutect2, varscan2
- MAP1B | c.3334G>A p.E1112K | Missense Mutation (SNP) | VAF 75/403 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- MAP3K14 | c.1958G>A p.R653Q | Missense Mutation (SNP) | VAF 62/300 reads (21%) | SIFT tolerated (0.56); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- MAP7D1 | c.2357A>G p.N786S | Missense Mutation (SNP) | VAF 183/395 reads (46%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MAP7D2 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 81/233 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MARCHF10 | c.1969G>A p.D657N | Missense Mutation (SNP) | VAF 132/391 reads (34%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MC5R | c.590T>A p.M197K | Missense Mutation (SNP) | VAF 72/252 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); called by muse, mutect2, varscan2
- MDN1 | c.5824G>A p.G1942R | Missense Mutation (SNP) | VAF 157/432 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.49); called by muse, mutect2, varscan2
- MGAM2 | c.3717G>A p.M1239I | Missense Mutation (SNP) | VAF 53/393 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- MICALL2 | c.1235G>A p.R412K | Missense Mutation (SNP) | VAF 159/542 reads (29%) | SIFT tolerated (0.96); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- MICU3 | c.1241G>A p.S414N | Missense Mutation (SNP) | VAF 28/184 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MMP27 | c.1426G>A p.D476N | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- MROH2A | c.1675G>A p.V559M | Missense Mutation (SNP) | VAF 15/378 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- MROH2B | c.1710G>A p.W570* | Nonsense Mutation (SNP) | VAF 61/185 reads (33%) | called by muse, mutect2, varscan2
- MROH5 | c.3235G>A p.G1079R | Missense Mutation (SNP) | VAF 138/235 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.072); called by muse, mutect2, varscan2
- MS4A4E | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 91/202 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- MUC1 | c.3704C>T p.P1235L (on ENST00000611571 / NM_001371720.1; = p.P246L on NM_002456.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 103/374 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MUC16 | c.40496C>T p.P13499L | Missense Mutation (SNP) | VAF 36/220 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MUC4 | c.7316C>T p.S2439F | Missense Mutation (SNP) | VAF 181/1089 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.496); called by muse, varscan2
- MUC5AC | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 84/339 reads (25%) | SIFT tolerated (0.11); called by muse, mutect2, varscan2
- MYL1 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 153/346 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MYSM1 | c.619C>T p.P207S | Missense Mutation (SNP) | VAF 85/466 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- MYT1L | c.519G>A p.M173I | Missense Mutation (SNP) | VAF 33/194 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- NBEA | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 65/224 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.118); called by muse, mutect2, varscan2
- NCKIPSD | c.2136G>T p.K712N | Missense Mutation (SNP) | VAF 147/327 reads (45%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- NDUFS1 | c.665T>C p.I222T | Missense Mutation (SNP) | VAF 62/305 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NHSL2 | c.544G>A p.E182K (on ENST00000510661; = p.E548K on NM_001013627.2) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NOL4 | c.1542G>A p.Q514= | Splice Region (SNP) | VAF 93/209 reads (44%) | called by muse, mutect2, varscan2
- NOVA1 | c.1208C>T p.S403F | Missense Mutation (SNP) | VAF 79/331 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- NPC1L1 | c.2414C>T p.S805F | Missense Mutation (SNP) | VAF 66/490 reads (13%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- NPIPB13 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 167/387 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- NTF3 | c.508G>A p.G170R | Missense Mutation (SNP) | VAF 82/262 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NUTM1 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 73/234 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- NXPH1 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 74/447 reads (17%) | called by muse, varscan2
- OBSCN | c.3761C>T p.P1254L | Missense Mutation (SNP) | VAF 30/197 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.262); called by muse, mutect2, varscan2
- OBSCN | c.14548G>A p.E4850K | Missense Mutation (SNP) | VAF 227/447 reads (51%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OLFML2A | c.814C>T p.L272F | Missense Mutation (SNP) | VAF 83/366 reads (23%) | SIFT tolerated (0.71); PolyPhen benign (0.155); called by muse, mutect2, varscan2
- OR10C1 | c.653C>T p.S218F (on ENST00000622521; = p.S216F on NM_013941.3) | Missense Mutation (SNP) | VAF 272/722 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- OR1J4 | c.446G>A p.W149* | Nonsense Mutation (SNP) | VAF 79/253 reads (31%) | called by muse, mutect2, varscan2
- OR1L3 | c.960A>C p.K320N | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by mutect2, varscan2
- OR1R1P | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 84/250 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.568); called by muse, mutect2, varscan2
- OR2A25 | c.67C>T p.Q23* | Nonsense Mutation (SNP) | VAF 65/465 reads (14%) | called by muse, mutect2, varscan2
- OR2T11 | c.866T>C p.L289P | Missense Mutation (SNP) | VAF 261/444 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- OR3A1 | c.24T>A p.N8K | Missense Mutation (SNP) | VAF 107/191 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- OR51E1 | c.562A>C p.M188L | Missense Mutation (SNP) | VAF 128/255 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- OR52E1 | c.496C>T p.P166S | Missense Mutation (SNP) | VAF 141/254 reads (56%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.279); called by muse, mutect2, varscan2
- OR5G3 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 124/213 reads (58%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- OR6A2 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 146/230 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR6C2 | c.40G>A p.G14R | Missense Mutation (SNP) | VAF 116/215 reads (54%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- OSBPL3 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 68/435 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OSMR | c.2104G>A p.D702N | Missense Mutation (SNP) | VAF 71/304 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OTUD7A | c.1573G>A p.G525S (on ENST00000307050 / NM_001382637.1; = p.G518S on NM_130901.3) | Missense Mutation (SNP) | VAF 156/480 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OXSR1 | c.1129C>T p.P377S | Missense Mutation (SNP) | VAF 48/246 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- P3H2 | c.718T>A p.Y240N | Missense Mutation (SNP) | VAF 75/361 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PALM3 | c.1333A>G p.T445A (on ENST00000340790; = p.T460A on NM_001145028.2) | Missense Mutation (SNP) | VAF 81/479 reads (17%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PARP14 | c.1423C>T p.P475S | Missense Mutation (SNP) | VAF 53/267 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PAX2 | c.812C>T p.P271L (on ENST00000428433 / NM_003987.5; = p.P248L on NM_000278.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 87/281 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- PCDHGA10 | c.200G>C p.G67A | Missense Mutation (SNP) | VAF 66/457 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- PCNT | c.1202C>T p.A401V | Missense Mutation (SNP) | VAF 40/158 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- PEX13 | c.506C>T p.S169F | Missense Mutation (SNP) | VAF 83/329 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- PHKA1 | c.2525A>T p.E842V | Missense Mutation (SNP) | VAF 59/143 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); called by muse, mutect2, varscan2
- PIWIL2 | c.1468G>A p.E490K | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- PKHD1 | c.1733G>A p.G578E | Missense Mutation (SNP) | VAF 68/445 reads (15%) | SIFT tolerated (0.33); PolyPhen benign (0.348); called by muse, mutect2, varscan2
- PLB1 | c.1184G>A p.G395E | Missense Mutation (SNP) | VAF 71/326 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- PLCB4 | c.3020C>T p.S1007L | Missense Mutation (SNP) | VAF 65/195 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PLXNA4 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- POLR3E | c.1565C>A p.S522Y | Missense Mutation (SNP) | VAF 98/476 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- POTEE | c.2035G>A p.D679N | Missense Mutation (SNP) | VAF 71/458 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- POTEF | c.2591C>T p.P864L | Missense Mutation (SNP) | VAF 90/520 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.625); called by muse, varscan2
- POTEF | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 16/32 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.218); called by mutect2, varscan2
- PPP4R3C | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 73/114 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PRDM6 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 122/199 reads (61%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- PREX2 | c.3019G>A p.D1007N | Missense Mutation (SNP) | VAF 78/412 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PRRC2C | c.6347C>T p.P2116L (on ENST00000367742; = p.P2114L on NM_015172.4) | Missense Mutation (SNP) | VAF 88/381 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRSS3 | c.108G>A p.W36* (on ENST00000361005 / NM_007343.4; = p.W144* on NM_002771.3) | Nonsense Mutation (SNP) | VAF 162/285 reads (57%) | called by muse, mutect2, varscan2
- PSG7 | c.449C>T p.S150F | Missense Mutation (SNP) | VAF 90/227 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- PTGER4 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 126/344 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PTGS1 | c.1294C>A p.R432= | Splice Region (SNP) | VAF 48/157 reads (31%) | called by muse, mutect2, varscan2
- PTPRH | c.1412T>C p.I471T | Missense Mutation (SNP) | VAF 47/282 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PUS7 | c.547C>T p.Q183* | Nonsense Mutation (SNP) | VAF 53/357 reads (15%) | called by muse, mutect2, varscan2
- PWP1 | c.716C>T p.S239L | Missense Mutation (SNP) | VAF 72/131 reads (55%) | SIFT tolerated (0.22); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- RALGAPA2 | c.5479C>T p.P1827S | Missense Mutation (SNP) | VAF 44/212 reads (21%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.466); called by muse, mutect2, varscan2
- RAPGEF1 | c.2167_2168insGGT p.T722_Y723insW | In Frame Ins (INS) | VAF 40/156 reads (26%) | called by mutect2, pindel, varscan2
- RBKS | c.410G>A p.R137K | Missense Mutation (SNP) | VAF 67/349 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RBM33 | c.2986G>A p.E996K | Missense Mutation (SNP) | VAF 59/377 reads (16%) | SIFT tolerated (0.27); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RCVRN | c.179C>T p.T60I | Missense Mutation (SNP) | VAF 180/310 reads (58%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, varscan2
- RECQL5 | c.2125C>T p.L709F | Missense Mutation (SNP) | VAF 102/688 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- RGS5 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 45/412 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); called by muse, varscan2
- RIMBP3 | c.3422C>T p.A1141V | Missense Mutation (SNP) | VAF 224/1457 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RIMS1 | c.120G>A p.M40I | Missense Mutation (SNP) | VAF 61/324 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.867); called by muse, mutect2, varscan2
- ROBO2 | c.2347G>A p.E783K | Missense Mutation (SNP) | VAF 53/238 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- RORC | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 56/483 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- RP1 | c.2189G>A p.G730E | Missense Mutation (SNP) | VAF 172/327 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RPH3A | c.1597G>A p.G533S (on ENST00000389385 / NM_001143854.2; = p.G529S on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 90/295 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- RPRD2 | c.3863C>T p.P1288L | Missense Mutation (SNP) | VAF 299/788 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, varscan2
- RPS6KA6 | c.1087G>A p.E363K | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- RRP1B | c.1745T>A p.L582H | Missense Mutation (SNP) | VAF 81/350 reads (23%) | SIFT tolerated (0.58); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- RSPO1 | c.646G>A p.G216S | Missense Mutation (SNP) | VAF 67/411 reads (16%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RTN4 | c.824A>G p.E275G | Missense Mutation (SNP) | VAF 73/301 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- RYR3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 54/218 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SAMD9 | c.4372C>T p.Q1458* | Nonsense Mutation (SNP) | VAF 67/432 reads (16%) | called by muse, mutect2, varscan2
- SCARA5 | c.403C>T p.Q135* | Nonsense Mutation (SNP) | VAF 208/577 reads (36%) | called by muse, varscan2
- SCIN | c.1658G>A p.W553* (on ENST00000297029 / NM_001112706.3; = p.W306* on NM_033128.3) | Nonsense Mutation (SNP) | VAF 134/456 reads (29%) | called by muse, mutect2, varscan2
- SCML2 | c.1920G>A p.M640I | Missense Mutation (SNP) | VAF 66/226 reads (29%) | SIFT tolerated (0.35); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- SCN2A | c.2171A>T p.K724I | Missense Mutation (SNP) | VAF 117/260 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SCN9A | c.2096C>A p.T699N (on ENST00000303354; = p.T688N on NM_002977.3) | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- SEC16B | c.209C>T p.P70L | Missense Mutation (SNP) | VAF 364/577 reads (63%) | SIFT deleterious (0.01); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SELP | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 127/497 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SEMA3G | c.767G>A p.G256D | Missense Mutation (SNP) | VAF 92/340 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- SEMA5A | c.1503C>A p.D501E | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); called by muse, mutect2
- SERPINB10 | c.514G>A p.D172N | Missense Mutation (SNP) | VAF 114/260 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.255); called by muse, varscan2
- SEZ6 | c.2262G>A p.W754* | Nonsense Mutation (SNP) | VAF 84/270 reads (31%) | called by muse, mutect2, varscan2
- SGIP1 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 141/298 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- SGSM2 | c.102T>G p.H34Q | Missense Mutation (SNP) | VAF 22/343 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- SHANK3 | c.4814C>T p.S1605F | Missense Mutation (SNP) | VAF 122/261 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- SHB | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 67/304 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- SHC4 | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 56/163 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- SLC25A6 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 116/707 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC26A5 | c.1436C>T p.S479F | Missense Mutation (SNP) | VAF 45/264 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- SLC34A1 | c.128G>A p.G43E | Missense Mutation (SNP) | VAF 193/310 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- SLC36A2 | c.525G>A p.Q175= | Splice Region (SNP) | VAF 124/182 reads (68%) | called by muse, mutect2, varscan2
- SLC4A4 | c.2423G>A p.R808K (on ENST00000264485 / NM_001098484.3; = p.R764K on NM_003759.4) | Missense Mutation (SNP) | VAF 51/247 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- SLC6A18 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 216/443 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- SLCO2A1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SLFN14 | c.2260C>T p.P754S | Missense Mutation (SNP) | VAF 72/292 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.444); called by muse, varscan2
- SLITRK6 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 53/333 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLITRK6 | c.19C>T p.L7F | Missense Mutation (SNP) | VAF 76/241 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLTM | c.1452T>A p.D484E | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SNX8 | c.848C>T p.S283F | Missense Mutation (SNP) | VAF 127/470 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SOX7 | c.520C>T p.L174F | Missense Mutation (SNP) | VAF 205/647 reads (32%) | SIFT tolerated (0.49); PolyPhen possibly damaging (0.532); called by muse, mutect2, varscan2
- SPINT1 | c.1442C>T p.A481V (on ENST00000344051 / NM_181642.3; = p.A465V on NM_003710.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 70/278 reads (25%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPTBN4 | c.4675-1G>A p.X1559_splice | Splice Site (SNP) | VAF 124/321 reads (39%) | called by muse, mutect2, varscan2
- SRP54 | c.66dup p.I23Yfs*3 | Frame Shift Ins (INS) | VAF 41/222 reads (18%) | called by mutect2, pindel, varscan2
- STAB2 | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 112/197 reads (57%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- STAB2 | c.2548G>A p.A850T | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.36); PolyPhen benign (0.214); called by muse, mutect2, varscan2
- STK26 | c.833C>T p.S278L | Missense Mutation (SNP) | VAF 53/101 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2828C>T p.S943F | Missense Mutation (SNP) | VAF 73/309 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.018); called by muse, mutect2, varscan2
506 further variants in this file (57 protein-altering or splice-affecting, 408 silent, 41 other) are not listed here.
